Somatic mutation profile of tumor specimen TCGA-D1-A163-01A (aliquot TCGA-D1-A163-01A-11D-A12J-09) from TCGA case TCGA-D1-A163, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 50.9 years (18,604 days).
Specimen TCGA-D1-A163-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eff3a34c-fdc8-4eac-b3e6-edc8a1dc52b8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A163-10A (Blood Derived Normal), aliquot TCGA-D1-A163-10A-01D-A12J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/797253b3-ca94-49d0-aa8d-ee2d0d0fa921

The open-access MAF lists 719 somatic variants for this specimen: 555 protein-altering or splice-affecting, 149 silent, 15 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 327, Frame Shift Del 153, Silent 149, Frame Shift Ins 34, Splice Site 13, Nonsense Mutation 13, In Frame Del 9, Splice Region 6, Intron 5, 3'UTR 4, 3'Flank 3, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC011462.1 | c.219dup p.R74Qfs*11 | Frame Shift Ins (INS) | VAF 26/73 reads (36%) | catalogued as rs398123489; ClinVar: pathogenic; called by mutect2, varscan2
- AGXT | c.33del p.K12Rfs*34 | Frame Shift Del (DEL) | VAF 26/31 reads (84%) | catalogued as rs180177201, CM056286; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ALOX12B | c.1350del p.L451Sfs*16 | Frame Shift Del (DEL) | VAF 35/111 reads (32%) | catalogued as rs746723399, COSV59872823; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CCND1 | c.857C>T p.T286I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV57119829, COSV99919330; called by muse, mutect2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 63/147 reads (43%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- HNF1A | c.130del p.L44Wfs*111 | Frame Shift Del (DEL) | VAF 8/14 reads (57%) | catalogued as rs193922578; ClinVar: pathogenic; called by mutect2, varscan2
- KANSL1 | c.2899del p.Q967Sfs*46 (on ENST00000574590 / NM_001193465.2; = p.Q968Sfs*46 on NM_015443.4) | Frame Shift Del (DEL) | VAF 30/90 reads (33%) | catalogued as rs1374665357; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 96/237 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MSH3 | c.1148del p.K383Rfs*32 | Frame Shift Del (DEL) | VAF 60/177 reads (34%) | catalogued as rs587776701; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 29/75 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs772110575, COSV55879949, COSV56003293; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3R1 | c.1746-2A>G p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 193/466 reads (41%) | hotspot (GDC flag); catalogued as COSV57125460, COSV57131831, COSV57142185; called by muse, mutect2, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 113/196 reads (58%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- ABCB1 | c.469C>T p.R157* | Nonsense Mutation (SNP) | VAF 40/250 reads (16%) | catalogued as rs1363838319, COSV55949125, COSV55958612; called by muse, mutect2, varscan2
- ABCC6 | c.2836del p.L946Sfs*23 | Frame Shift Del (DEL) | VAF 6/17 reads (35%) | catalogued as CM034642; called by mutect2, varscan2
- ABCF3 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 91/236 reads (39%) | catalogued as rs1339124014, COSV53047738; called by muse, mutect2, varscan2
- AC131160.1 | c.1046G>T p.W349L | Missense Mutation (SNP) | VAF 63/163 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV59414325; called by muse, mutect2, varscan2
- ACCS | c.83A>G p.H28R | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.015); catalogued as COSV55457876; called by muse, mutect2, varscan2
- ACHE | c.1821G>T p.K607N | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53816792; called by muse, mutect2, varscan2
- ACKR4 | c.563T>C p.F188S | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1221481797, COSV51442384; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 74/175 reads (42%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADCY9 | c.331C>T p.Q111* | Nonsense Mutation (SNP) | VAF 25/68 reads (37%) | catalogued as COSV53574198; called by muse, mutect2, varscan2
- ADGRG4 | c.108dup p.G37Wfs*4 | Frame Shift Ins (INS) | VAF 18/54 reads (33%) | catalogued as rs1238901032; called by mutect2, varscan2
- ADNP | c.3047del p.K1016Rfs*11 | Frame Shift Del (DEL) | VAF 54/134 reads (40%) | catalogued as rs761350619; called by mutect2, varscan2
- AFF1 | c.3158G>A p.R1053H | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754441802, COSV57118594; called by muse, mutect2, varscan2
- AFF4 | c.412G>A p.A138T | Missense Mutation (SNP) | VAF 120/272 reads (44%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs756072790, COSV54793809; called by muse, mutect2, varscan2
- AGBL5 | c.2093C>A p.P698H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.754); catalogued as COSV64079560; called by muse, mutect2, varscan2
- AHNAK2 | c.15586C>T p.R5196C | Missense Mutation (SNP) | VAF 41/100 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.731); catalogued as rs1418692346, COSV60913148; called by muse, mutect2, varscan2
- AHNAK2 | c.12805G>A p.E4269K | Missense Mutation (SNP) | VAF 88/201 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs755133395, COSV60913165; called by muse, mutect2, varscan2
- AKNA | c.2003C>T p.P668L | Missense Mutation (SNP) | VAF 76/170 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs766859655, COSV56312207; called by muse, mutect2, varscan2
- ALDH16A1 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.873); catalogued as COSV53193632; called by muse, mutect2, varscan2
- ALDH8A1 | c.1377del p.M460* | Frame Shift Del (DEL) | VAF 86/239 reads (36%) | catalogued as rs1423245247, COSV99664569; called by mutect2, pindel, varscan2
- AMIGO2 | c.1271G>A p.C424Y | Missense Mutation (SNP) | VAF 139/323 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56973924; called by muse, mutect2, varscan2
- ANGEL2 | c.1477C>T p.H493Y | Missense Mutation (SNP) | VAF 67/197 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV64737217; called by muse, mutect2, varscan2
- ANKK1 | c.1096del p.L366Sfs*13 | Frame Shift Del (DEL) | VAF 27/111 reads (24%) | catalogued as rs755428982; called by mutect2, pindel, varscan2
- ANKLE2 | c.2690C>T p.P897L | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.614); catalogued as rs201716997, COSV63294550; called by muse, mutect2, varscan2
- ANO4 | c.790G>A p.V264M (on ENST00000392977 / NM_001286615.2; = p.V229M on NM_178826.4) | Missense Mutation (SNP) | VAF 64/178 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as rs533844889, COSV54592843; called by muse, mutect2, varscan2
- APBA2 | c.1462C>T p.P488S | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.18); catalogued as rs1413505682, COSV67104580; called by muse, mutect2, varscan2
- ARC | c.1034T>C p.L345P | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV63078372, COSV63078393; called by muse, mutect2, varscan2
- AREL1 | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.893); catalogued as rs560391293, COSV62666145; called by muse, mutect2, varscan2
- ARHGAP35 | c.2594_2608del p.A865_L870delinsV | In Frame Del (DEL) | VAF 78/232 reads (34%) | catalogued as COSV68330482; called by mutect2, pindel, varscan2
- ARHGEF40 | c.4553C>A p.P1518H | Missense Mutation (SNP) | VAF 87/221 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53879594; called by muse, mutect2, varscan2
- ARHGEF5 | c.4687G>A p.V1563M | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as rs1163111473, COSV50209373; called by muse, mutect2, varscan2
- ARID3A | c.1496-2A>G p.X499_splice | Splice Site (SNP) | VAF 22/61 reads (36%) | catalogued as COSV55043815, COSV55044153; called by muse, mutect2, varscan2
- ARMCX5-GPRASP2 | c.50del p.K17Rfs*21 | Frame Shift Del (DEL) | VAF 35/97 reads (36%) | catalogued as rs1290336606; called by mutect2, pindel, varscan2
- ASCC3 | c.762G>A p.M254I | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV61227779; called by muse, mutect2, varscan2
- ASH1L | c.3449C>T p.A1150V | Missense Mutation (SNP) | VAF 14/150 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs371551723, COSV64207195; called by muse, mutect2
- ATF5 | c.109del p.L37Wfs*31 | Frame Shift Del (DEL) | VAF 15/28 reads (54%) | catalogued as rs768611141; called by mutect2, varscan2
- ATG4B | c.952G>A p.A318T | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1402382749, COSV60350560; called by muse, mutect2, varscan2
- ATG9B | c.293del p.P98Qfs*8 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | catalogued as rs770350293; called by mutect2, pindel, varscan2
- ATP2C1 | c.1173T>A p.D391E | Missense Mutation (SNP) | VAF 179/491 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60755372; called by muse, mutect2, varscan2
- ATR | c.5440del p.R1814Efs*10 | Frame Shift Del (DEL) | VAF 64/154 reads (42%) | catalogued as rs1268253442; called by mutect2, varscan2
- AXIN1 | c.1017C>T p.S339= | Splice Region (SNP) | VAF 29/70 reads (41%) | catalogued as rs771205530, COSV51986145; called by muse, mutect2, varscan2
- BAZ2A | c.3062C>T p.A1021V | Missense Mutation (SNP) | VAF 43/130 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.828); catalogued as COSV51635075; called by muse, mutect2, varscan2
- BRWD3 | c.1127G>A p.S376N | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); catalogued as COSV64746842; called by muse, mutect2
- BSN | c.9179C>T p.A3060V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV56516195; called by muse, mutect2, varscan2
- C11orf42 | c.287G>A p.C96Y | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.994); catalogued as COSV56410860; called by muse, mutect2, varscan2
- C1orf112 | c.1235C>T p.A412V | Missense Mutation (SNP) | VAF 182/483 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.16); catalogued as COSV53678050; called by muse, mutect2, varscan2
- C5orf34 | c.1631C>A p.P544H | Missense Mutation (SNP) | VAF 56/121 reads (46%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.594); catalogued as COSV60929600; called by muse, mutect2, varscan2
- C6 | c.828del p.S277Afs*43 | Frame Shift Del (DEL) | VAF 118/333 reads (35%) | catalogued as rs372345940, CD982526, COSV54718324; called by mutect2, pindel, varscan2
- C7orf50 | c.535dup p.L179Pfs*54 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | catalogued as rs750339990; called by mutect2, varscan2
- CAMSAP2 | c.4309del p.M1437* (on ENST00000236925 / NM_001297707.2; = p.M1426* on NM_203459.3) | Frame Shift Del (DEL) | VAF 34/123 reads (28%) | catalogued as rs1375954479; called by mutect2, pindel, varscan2
- CAMSAP3 | c.3463G>A p.A1155T | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50332739; called by muse, mutect2, varscan2
- CAPN7 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 41/279 reads (15%) | catalogued as rs755151623, COSV53777783; called by muse, mutect2, varscan2
- CARD11 | c.2074G>A p.V692M | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as rs587778151, COSV62754292; ClinVar: not provided; called by muse, mutect2, varscan2
- CARS1 | c.2061dup p.S688Qfs*2 | Frame Shift Ins (INS) | VAF 47/147 reads (32%) | catalogued as rs753057519; called by mutect2, pindel, varscan2
- CASKIN1 | c.1667C>T p.A556V | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV58213906; called by muse, mutect2, varscan2
- CBX7 | c.622C>G p.P208A | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.024); catalogued as COSV53358809, COSV53359400, COSV53359594; called by muse, mutect2, varscan2
- CCDC191 | c.2768C>T p.S923L | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV55671577; called by muse, mutect2, varscan2
- CCND3 | c.859G>A p.V287I | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.108); catalogued as COSV57828311; called by muse, mutect2, varscan2
- CD109 | c.3856G>A p.A1286T | Missense Mutation (SNP) | VAF 86/217 reads (40%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV54648250; called by muse, mutect2, varscan2
- CDC42EP1 | c.373C>T p.L125F | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50756255; called by muse, mutect2, varscan2
- CDH19 | c.959del p.K320Rfs*27 | Frame Shift Del (DEL) | VAF 80/206 reads (39%) | catalogued as rs1322953086; called by mutect2, pindel, varscan2
- CDH2 | c.2633G>T p.S878I | Missense Mutation (SNP) | VAF 29/203 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52277819; called by muse, mutect2, varscan2
- CDK10 | c.280C>T p.R94C (on ENST00000353379 / NM_052988.5; = p.R23C on NM_052987.4) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as rs184050237; called by muse, mutect2, varscan2
- CDK17 | c.961A>G p.I321V | Missense Mutation (SNP) | VAF 203/441 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54128315; called by muse, mutect2, varscan2
- CDKAL1 | c.1645A>G p.M549V | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV51182235; called by muse, mutect2, varscan2
- CDKL5 | c.1738A>G p.S580G | Missense Mutation (SNP) | VAF 9/254 reads (4%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV66110899; called by muse, mutect2
- CEACAM19 | c.445A>G p.S149G | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.42); PolyPhen benign (0.026); catalogued as rs760244702, COSV62551934; called by muse, mutect2, varscan2
- CENPC | c.616del p.R206Gfs*2 | Frame Shift Del (DEL) | VAF 49/128 reads (38%) | catalogued as rs1325731082; called by mutect2, pindel, varscan2
- CEP290 | c.635del p.N212Tfs*14 | Frame Shift Del (DEL) | VAF 145/367 reads (40%) | catalogued as rs769091629, COSV99063658; called by mutect2, varscan2
- CFAP97 | c.580G>C p.D194H | Missense Mutation (SNP) | VAF 103/303 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV57110108; called by muse, mutect2, varscan2
- CHIC1 | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV65156081; called by muse, mutect2, varscan2
- CHST5 | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); catalogued as rs778221590, COSV60338588; called by muse, mutect2
- CLASRP | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); catalogued as rs865988597, COSV55515681; called by muse, mutect2, varscan2
- CLIP3 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV62112288; called by muse, varscan2
- CNNM1 | c.2357A>G p.Y786C | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1449651435, COSV63201244; called by muse, mutect2, varscan2
- CNTN3 | c.1936G>A p.V646I | Missense Mutation (SNP) | VAF 208/487 reads (43%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs148089886; called by muse, mutect2, varscan2
- CNTNAP2 | c.3227C>T p.A1076V | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV62168239; called by muse, varscan2
- COASY | c.537del p.V180Wfs*47 | Frame Shift Del (DEL) | VAF 21/49 reads (43%) | catalogued as COSV55900587; called by mutect2, pindel, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 46/66 reads (70%) | catalogued as rs374805044; called by mutect2, varscan2
- COCH | c.1337G>A p.S446N (on ENST00000216361 / NM_001347720.1; = p.S381N on NM_004086.3) | Missense Mutation (SNP) | VAF 71/181 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV53550399; called by muse, mutect2, varscan2
- COL3A1 | c.1293+1G>A p.X431_splice | Splice Site (SNP) | VAF 57/125 reads (46%) | catalogued as COSV58585800; called by muse, mutect2, varscan2
- COL6A2 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs139627965, COSV56015899; called by muse, mutect2, varscan2
- COX6A2 | c.259G>A p.V87M | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV54931757; called by muse, mutect2, varscan2
- COX7A1 | c.26C>A p.A9E | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.237); catalogued as COSV53084595; called by muse, mutect2, varscan2
- CRABP2 | c.179G>A p.R60H | Missense Mutation (SNP) | VAF 111/279 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs548565052, COSV63958863; called by muse, mutect2, varscan2
- CRELD2 | c.291G>T p.Q97H | Missense Mutation (SNP) | VAF 50/125 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58206756, COSV58207284; called by muse, mutect2, varscan2
- CRHR1 | c.383G>A p.C128Y | Missense Mutation (SNP) | VAF 60/166 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV53277617; called by muse, mutect2, varscan2
- CSF3R | c.1404del p.S469Afs*22 | Frame Shift Del (DEL) | VAF 38/107 reads (36%) | catalogued as rs747437399; called by mutect2, pindel, varscan2
- CSMD1 | c.3482A>G p.Y1161C (on ENST00000520002; = p.Y1160C on NM_033225.6) | Missense Mutation (SNP) | VAF 78/198 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV59310096; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 59/186 reads (32%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CTC1 | c.3157-2A>G p.X1053_splice | Splice Site (SNP) | VAF 60/159 reads (38%) | catalogued as rs200350451, COSV59852976; called by muse, mutect2, varscan2
- CTNNBL1 | c.172del p.R58Gfs*25 | Frame Shift Del (DEL) | VAF 63/192 reads (33%) | catalogued as rs761516328; called by mutect2, pindel, varscan2
- CUX1 | c.2786del p.P929Rfs*2 | Frame Shift Del (DEL) | VAF 47/138 reads (34%) | catalogued as rs1563399735; called by mutect2, pindel, varscan2
- CYGB | c.410A>C p.E137A | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV53150058; called by muse, mutect2
- CYP2C9 | c.169-2A>T p.X57_splice | Splice Site (SNP) | VAF 232/909 reads (26%) | catalogued as COSV53247940, COSV53254372; called by muse, mutect2, varscan2
- CYP39A1 | c.1205A>G p.D402G | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV51494902; called by muse, mutect2, varscan2
- CYP4A22 | c.1430G>A p.R477H | Missense Mutation (SNP) | VAF 68/172 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.103); catalogued as rs377247931; called by muse, mutect2, varscan2
- DCAF11 | c.1303G>A p.G435R | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); catalogued as rs1390286215, CM143141, COSV58108490; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 46/118 reads (39%) | catalogued as rs766714372; called by mutect2, varscan2
- DDX50 | c.1017dup p.Y340Ifs*7 | Frame Shift Ins (INS) | VAF 52/140 reads (37%) | catalogued as rs747282010; called by mutect2, varscan2
- DECR2 | c.331A>G p.I111V | Missense Mutation (SNP) | VAF 93/246 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.015); catalogued as rs754566704, COSV54794040; called by muse, mutect2, varscan2
- DGCR8 | c.1259T>C p.L420P | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV61226352; called by muse, mutect2, varscan2
- DHDDS | c.466T>C p.Y156H | Missense Mutation (SNP) | VAF 111/318 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52576213; called by muse, mutect2, varscan2
- DHX16 | c.980G>A p.R327Q | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs1347907322, COSV64563664; called by muse, mutect2, varscan2
- DHX36 | c.460del p.M154Cfs*27 | Frame Shift Del (DEL) | VAF 88/214 reads (41%) | catalogued as rs373108427; called by mutect2, varscan2
- DIO2 | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.596); catalogued as rs1448729237, COSV70445067; called by muse, mutect2, varscan2
- DIP2B | c.2641G>A p.V881M | Missense Mutation (SNP) | VAF 142/329 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746963040, COSV56582480; called by muse, mutect2, varscan2
- DLC1 | c.2968G>T p.A990S (on ENST00000276297 / NM_001348081.2; = p.A553S on NM_006094.5) | Missense Mutation (SNP) | VAF 28/164 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as COSV52299773; called by muse, mutect2, varscan2
- DLGAP2 | c.766G>A p.G256S | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs763207744, COSV70097076; called by muse, mutect2, varscan2
- DLGAP4 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs747868912, COSV59415579; called by muse, mutect2, varscan2
- DNAH10 | c.12934A>G p.K4312E (on ENST00000409039; = p.K4251E on NM_207437.3) | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.139); catalogued as COSV53019399; called by muse, mutect2, varscan2
- DNAJB12 | c.1133G>A p.R378H (on ENST00000338820; = p.R344H on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs1187765966, COSV58760231; called by muse, mutect2, varscan2
- DOK4 | c.949del p.D317Tfs*19 | Frame Shift Del (DEL) | VAF 52/185 reads (28%) | catalogued as rs755984331; called by mutect2, pindel, varscan2
- DPY19L1 | c.191T>C p.M64T | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV60581828; called by muse, mutect2, varscan2
- DYNC2H1 | c.12480del p.K4160Nfs*42 | Frame Shift Del (DEL) | VAF 95/281 reads (34%) | catalogued as COSV62086408; called by mutect2, pindel, varscan2
- EBF2 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV68777135; called by muse, mutect2, varscan2
- EBNA1BP2 | c.433C>A p.L145M | Missense Mutation (SNP) | VAF 109/261 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.447); catalogued as COSV52539813, COSV52539902; called by muse, mutect2, varscan2
- EFCAB12 | c.1420A>C p.S474R | Missense Mutation (SNP) | VAF 170/436 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.029); catalogued as COSV58175991; called by muse, mutect2, varscan2
- EHHADH | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs780567517, COSV51629346; called by muse, mutect2, varscan2
- EIF2AK3 | c.1622G>A p.R541H | Missense Mutation (SNP) | VAF 108/278 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs758957898, COSV57546690; called by muse, mutect2, varscan2
- EMILIN2 | c.2963_2964del p.E988Vfs*47 | Frame Shift Del (DEL) | VAF 16/59 reads (27%) | catalogued as rs1568489275; called by pindel, varscan2
- EMILIN3 | c.1380dup p.W461Vfs*31 | Frame Shift Ins (INS) | VAF 34/88 reads (39%) | catalogued as rs759858342; called by mutect2, varscan2
- EMP2 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.059); catalogued as rs768678154, COSV59821215; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 112/302 reads (37%) | catalogued as rs753821453; called by mutect2, varscan2
- EXTL1 | c.1663G>A p.A555T | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65332564; called by muse, mutect2, varscan2
- F10 | c.1028T>C p.L343P | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65021417; called by muse, mutect2, varscan2
- F13B | c.265+1G>A p.X89_splice | Splice Site (SNP) | VAF 54/130 reads (42%) | catalogued as COSV66373416; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 69/235 reads (29%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FAM47A | c.2182G>A p.D728N | Missense Mutation (SNP) | VAF 136/363 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV60495808; called by muse, mutect2, varscan2
- FAM47B | c.575C>T p.P192L | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV61452653; called by muse, mutect2, varscan2
- FAM47B | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.41); PolyPhen benign (0.036); catalogued as rs1267449984, COSV61453349; called by muse, mutect2, varscan2
- FAM78B | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57976264; called by muse, mutect2
- FAM83B | c.1996C>T p.P666S | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV60921331; called by muse, mutect2
- FAM83D | c.1543del p.H515Tfs*6 | Frame Shift Del (DEL) | VAF 37/126 reads (29%) | catalogued as rs754952124; called by mutect2, pindel, varscan2
- FAM9A | c.477del p.K159Nfs*3 | Frame Shift Del (DEL) | VAF 239/574 reads (42%) | catalogued as rs748967872; called by mutect2, varscan2
- FARP1 | c.1978C>T p.R660W | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs145494993; called by muse, mutect2, varscan2
- FARP1 | c.2888_2890del p.F963del | In Frame Del (DEL) | VAF 60/153 reads (39%) | catalogued as rs1390774650; called by pindel, varscan2
- FASN | c.2225C>A p.P742H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60753283; called by muse, mutect2, varscan2
- FBXW2 | c.820-1G>T p.X274_splice | Splice Site (SNP) | VAF 40/121 reads (33%) | catalogued as COSV61596786; called by muse, mutect2, varscan2
- FCGBP | c.5446G>A p.G1816S | Missense Mutation (SNP) | VAF 78/188 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1440002489; called by mutect2, varscan2
- FGD2 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV51463197; called by muse, mutect2
- FHOD3 | c.3757T>C p.Y1253H (on ENST00000359247 / NM_001281739.3; = p.Y1270H on NM_025135.5) | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57170992; called by muse, mutect2, varscan2
- FKTN | c.851C>T p.A284V | Missense Mutation (SNP) | VAF 32/228 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.322); catalogued as COSV56309277; called by muse, mutect2, varscan2
- FMNL3 | c.1354C>T p.H452Y | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as COSV53300670; called by muse, mutect2, varscan2
- FNTB | c.615C>A p.Y205* | Nonsense Mutation (SNP) | VAF 23/109 reads (21%) | catalogued as COSV55761032; called by muse, mutect2, varscan2
- FXR1 | c.371del p.N124Ifs*14 | Frame Shift Del (DEL) | VAF 58/158 reads (37%) | catalogued as rs756304971; called by mutect2, varscan2
- FZD3 | c.907T>A p.W303R | Missense Mutation (SNP) | VAF 30/170 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53535169; called by muse, mutect2, varscan2
- GABRA6 | c.467G>A p.C156Y | Missense Mutation (SNP) | VAF 53/320 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50879724; called by muse, mutect2, varscan2
- GABRD | c.893G>A p.R298H | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66080349; called by muse, mutect2, varscan2
- GLRA1 | c.721C>T p.R241W | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.994); catalogued as rs776919102, COSV51010950, COSV51025851; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GNG13 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 60/169 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.175); catalogued as rs186803817; called by muse, mutect2, varscan2
- GON4L | c.5857G>T p.G1953W | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as COSV55191929; called by muse, mutect2, varscan2
- GPR1 | c.727A>G p.R243G | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.012); catalogued as rs1339865297, COSV67976712; called by muse, mutect2, varscan2
- GPR151 | c.95C>A p.S32Y | Missense Mutation (SNP) | VAF 69/157 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV57036370; called by muse, mutect2
- GPR31 | c.319G>A p.A107T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.495); catalogued as rs1247441482, COSV64761331; called by muse, mutect2, varscan2
- GPR84 | c.82del p.V28Wfs*5 | Frame Shift Del (DEL) | VAF 51/141 reads (36%) | catalogued as rs759103894; called by mutect2, pindel, varscan2
- GRM1 | c.839G>T p.R280M | Missense Mutation (SNP) | VAF 31/155 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51130512; called by muse, varscan2
- GRM8 | c.2158del p.H720Tfs*12 | Frame Shift Del (DEL) | VAF 47/150 reads (31%) | catalogued as COSV58842099; called by mutect2, pindel, varscan2
- GRTP1 | c.196C>T p.R66W | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376648575; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 22/43 reads (51%) | catalogued as rs754199513; called by mutect2, varscan2
- GTF2IRD1 | c.227C>T p.A76V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV56085950; called by muse, mutect2, varscan2
- GUCY1A2 | c.1778C>T p.A593V | Missense Mutation (SNP) | VAF 61/139 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.481); catalogued as rs776184273, COSV56484166; called by muse, mutect2, varscan2
- H1-0 | c.230C>T p.T77I | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.148); catalogued as COSV50648867; called by muse, mutect2, varscan2
- H2AC11 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 20/186 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV60361980; called by muse, mutect2, varscan2
- H2BC14 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 99/249 reads (40%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.015); catalogued as rs764475448, COSV60797525; called by muse, mutect2, varscan2
- HARS2 | c.1139G>A p.C380Y | Missense Mutation (SNP) | VAF 71/163 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51226926; called by muse, mutect2, varscan2
- HBS1L | c.1196C>T p.T399M | Missense Mutation (SNP) | VAF 23/163 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747560815, COSV63201045; called by muse, mutect2, varscan2
- HDAC5 | c.2793del p.I932Lfs*14 | Frame Shift Del (DEL) | VAF 11/39 reads (28%) | catalogued as COSV52242263; called by mutect2, pindel, varscan2
- HEATR1 | c.5755C>T p.L1919= | Splice Region (SNP) | VAF 56/149 reads (38%) | catalogued as COSV63980734; called by muse, mutect2, varscan2
- HGSNAT | c.564T>C p.S188= | Splice Region (SNP) | VAF 36/86 reads (42%) | catalogued as COSV65533068, COSV65535842; called by muse, mutect2, varscan2
- HIPK2 | c.1871C>T p.A624V | Missense Mutation (SNP) | VAF 10/195 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs1020138286, COSV61226980; called by muse, mutect2
- HIVEP3 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56013702; called by muse, mutect2, varscan2
- HOMEZ | c.1127del p.L376Yfs*14 | Frame Shift Del (DEL) | VAF 154/331 reads (47%) | catalogued as rs755016625; called by mutect2, varscan2
- HS6ST3 | c.1255T>C p.Y419H | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV65006756; called by muse, mutect2, varscan2
- HSPG2 | c.8404C>A p.L2802M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.555); catalogued as COSV65970789; called by muse, mutect2, varscan2
- HTR1F | c.930del p.F310Lfs*2 | Frame Shift Del (DEL) | VAF 70/182 reads (38%) | catalogued as rs748579647; called by mutect2, pindel, varscan2
- HYOU1 | c.1787A>G p.N596S | Missense Mutation (SNP) | VAF 65/175 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV68215583; called by muse, mutect2, varscan2
- IDH1 | c.13del p.I5Sfs*7 | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | catalogued as COSV61630505; called by mutect2, pindel
- IDH3G | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.044); catalogued as rs1161222789, COSV54207084; called by muse, mutect2, varscan2
- IL4R | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 63/126 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.293); catalogued as COSV50141099; called by muse, mutect2, varscan2
- INTS13 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 147/388 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs777593850, COSV53901510, COSV53902785; called by muse, mutect2, varscan2
- INTS3 | c.1702A>G p.T568A | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT tolerated (0.27); PolyPhen benign (0.123); catalogued as COSV59676796; called by muse, mutect2, varscan2
- ITGB3 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 58/153 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774332906, COSV71383559; called by muse, mutect2, varscan2
- KCNG2 | c.1066G>A p.V356M | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs1430987118, COSV60267400; called by muse, mutect2, varscan2
- KCTD16 | c.1149del p.A384Lfs*20 | Frame Shift Del (DEL) | VAF 45/97 reads (46%) | catalogued as rs753765917, COSV72577101; called by mutect2, varscan2
- KIF12 | c.1934G>A p.G645D (on ENST00000640217; = p.G507D on NM_138424.1) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.009); catalogued as rs774745624, COSV65117051; called by muse, mutect2, varscan2
- KIF1A | c.2230A>G p.K744E | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.236); catalogued as COSV57486918; called by muse, mutect2, varscan2
- KIF2B | c.1510C>T p.R504W | Missense Mutation (SNP) | VAF 65/136 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757000396, COSV52127134; called by muse, mutect2, varscan2
- KIF4A | c.2182C>T p.R728W | Missense Mutation (SNP) | VAF 86/212 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240274269, COSV65542698; called by muse, varscan2
- KIRREL2 | c.1210C>A p.L404M | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV52875663; called by muse, mutect2, varscan2
- KIT | c.611T>C p.V204A | Missense Mutation (SNP) | VAF 29/143 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV55396782; called by muse, mutect2, varscan2
- KLC1 | c.644C>T p.T215M | Missense Mutation (SNP) | VAF 7/10 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs1567022490, COSV55807288; called by muse, mutect2, varscan2
- KLHDC2 | c.1175A>G p.H392R | Missense Mutation (SNP) | VAF 59/148 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.142); catalogued as COSV53587049; called by muse, mutect2, varscan2
- KLHL11 | c.2077C>T p.R693C | Missense Mutation (SNP) | VAF 81/182 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs782484417, COSV59861795, COSV59862740; called by muse, mutect2, varscan2
- KLK10 | c.349G>T p.V117F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV59397198; called by muse, mutect2, varscan2
- KLKB1 | c.1169G>A p.R390H | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369481447; called by muse, mutect2, varscan2
- KMO | c.374A>G p.Y125C | Missense Mutation (SNP) | VAF 109/267 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs751506463, COSV63807568; called by muse, mutect2, varscan2
- KNTC1 | c.1953G>T p.E651D | Missense Mutation (SNP) | VAF 95/238 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.075); catalogued as COSV61079729, COSV61079970; called by muse, mutect2, varscan2
- KPNA1 | c.1184G>A p.R395Q | Missense Mutation (SNP) | VAF 101/224 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.396); catalogued as COSV60268534; called by muse, mutect2, varscan2
- KRT31 | c.750+2T>C p.X250_splice | Splice Site (SNP) | VAF 42/217 reads (19%) | catalogued as COSV52434544; called by muse, mutect2, varscan2
- KRT6B | c.1243C>T p.R415C | Missense Mutation (SNP) | VAF 88/203 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); catalogued as rs556860047, COSV52883214; called by muse, mutect2, varscan2
- KSR1 | c.1388C>T p.P463L (on ENST00000644974 / NM_001367810.1; = p.P326L on NM_014238.2) | Missense Mutation (SNP) | VAF 126/330 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.049); catalogued as rs748540540, COSV52031003; called by muse, mutect2, varscan2
- LATS1 | c.1986del p.K662Nfs*3 | Frame Shift Del (DEL) | VAF 46/129 reads (36%) | catalogued as COSV53600967; called by mutect2, pindel, varscan2
- LGI3 | c.1297C>T p.R433C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs753302293, COSV60443225; called by muse, mutect2, varscan2
- LPAR1 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 39/362 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV62688291; called by muse, mutect2
- LPP | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 55/127 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57086965; called by muse, mutect2, varscan2
- LRP2 | c.9478C>T p.P3160S | Missense Mutation (SNP) | VAF 8/226 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1424345675, COSV55549643; called by muse, mutect2
- LRRK1 | c.2579G>A p.R860H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs142470911; called by muse, mutect2, varscan2
- LYPLA2 | c.176C>T p.A59V | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); catalogued as COSV55754771; called by muse, mutect2, varscan2
- LYRM2 | c.73_75del p.L25del | In Frame Del (DEL) | VAF 41/290 reads (14%) | catalogued as rs764905689; called by pindel, varscan2
- LYST | c.3686C>A p.P1229H | Missense Mutation (SNP) | VAF 35/238 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV67706118; called by muse, mutect2, varscan2
- MAMDC4 | c.3538_3540del p.K1180del (on ENST00000445819; = p.K1101del on NM_206920.3) | In Frame Del (DEL) | VAF 16/48 reads (33%) | catalogued as rs769057784; called by pindel, varscan2
- MAMLD1 | c.576T>G p.N192K | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV53373888; called by muse, mutect2, varscan2
- MAOB | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65204929; called by muse, mutect2, varscan2
- MAP3K10 | c.791C>A p.A264E | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53421708; called by muse, mutect2
- MAP4K4 | c.771del p.K257Nfs*10 | Frame Shift Del (DEL) | VAF 82/238 reads (34%) | catalogued as rs774203808; called by mutect2, pindel, varscan2
- MAPK8IP2 | c.470G>A p.G157D | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.444); catalogued as COSV50496627; called by muse, mutect2, varscan2
- MAPKAPK3 | c.635A>G p.E212G | Missense Mutation (SNP) | VAF 63/187 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63597211; called by muse, mutect2, varscan2
- MBD5 | c.3637G>A p.E1213K | Missense Mutation (SNP) | VAF 42/105 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs1219291357, COSV68696603; called by muse, mutect2, varscan2
- MDGA1 | c.88G>A p.V30M | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.313); catalogued as rs755556368, COSV51794731; called by muse, mutect2, varscan2
- MED15 | c.1357del p.Q453Sfs*41 (on ENST00000263205 / NM_001003891.3; = p.Q413Sfs*41 on NM_015889.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 9/15 reads (60%) | catalogued as COSV99487865; called by mutect2, varscan2
- MEGF8 | c.1717C>T p.R573W | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as rs369696855; called by muse, mutect2, varscan2
- MGA | c.83T>C p.L28S | Missense Mutation (SNP) | VAF 57/166 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54952187; called by muse, mutect2, varscan2
- MGAM | c.1542T>G p.F514L | Missense Mutation (SNP) | VAF 134/354 reads (38%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV72074460; called by muse, mutect2, varscan2
- MIDEAS | c.1808G>A p.R603Q | Missense Mutation (SNP) | VAF 49/116 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV54094153; called by muse, mutect2, varscan2
- MIPEP | c.1297A>G p.I433V | Missense Mutation (SNP) | VAF 83/193 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV66300311; called by muse, mutect2, varscan2
- MKI67 | c.698del p.N233Mfs*12 | Frame Shift Del (DEL) | VAF 99/278 reads (36%) | catalogued as rs749903408; called by mutect2, varscan2
- MORC4 | c.2054_2056del p.E685del | In Frame Del (DEL) | VAF 84/278 reads (30%) | catalogued as rs1399025642; called by pindel, varscan2
- MTFR1L | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); catalogued as rs770267388, COSV65355381; called by muse, mutect2, varscan2
- MTSS1 | c.1918C>T p.R640W | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.145); catalogued as rs762528178, COSV52674772; called by muse, mutect2, varscan2
- MUC5B | c.15526G>A p.V5176M | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as rs780193759, COSV71591367; called by muse, mutect2
- MYBPC3 | c.2689G>T p.G897* | Nonsense Mutation (SNP) | VAF 7/23 reads (30%) | catalogued as COSV57026037; called by muse, mutect2, varscan2
- MYO10 | c.1238T>C p.V413A | Missense Mutation (SNP) | VAF 82/225 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV72563021; called by muse, mutect2, varscan2
- MYO5A | c.833G>C p.R278P | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as COSV62559131, COSV62561475; called by muse, mutect2, varscan2
- NAGA | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.159); catalogued as rs368177710; called by muse, mutect2, varscan2
- NANS | c.938C>T p.T313I | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.548); catalogued as rs563059238, COSV52963523; called by muse, mutect2, varscan2
- NBEA | c.4601C>T p.P1534L | Missense Mutation (SNP) | VAF 190/422 reads (45%) | SIFT tolerated (0.91); PolyPhen benign (0.009); catalogued as rs773958544, COSV59777063, COSV59801297; called by muse, mutect2, varscan2
- NCAPD2 | c.3517C>T p.R1173C | Missense Mutation (SNP) | VAF 62/139 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766002564, COSV57520849; called by muse, mutect2, varscan2
- NCOR2 | c.108C>T p.D36= | Splice Region (SNP) | VAF 31/69 reads (45%) | catalogued as rs371190775; called by muse, mutect2, varscan2
- NEB | c.2947A>G p.K983E | Missense Mutation (SNP) | VAF 153/365 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV51113528; called by muse, mutect2, varscan2
- NKAP | c.470C>T p.S157F | Missense Mutation (SNP) | VAF 73/176 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV65056119; called by muse, mutect2, varscan2
- NKPD1 | c.1498G>A p.A500T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.619); catalogued as COSV58728594; called by muse, mutect2, varscan2
- NRP1 | c.1577G>A p.W526* | Nonsense Mutation (SNP) | VAF 8/154 reads (5%) | catalogued as COSV55164273; called by muse, mutect2
- NRXN1 | c.2549G>A p.G850D | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58446753; called by muse, mutect2, varscan2
- NRXN1 | c.1851dup p.L618Afs*5 | Frame Shift Ins (INS) | VAF 48/148 reads (32%) | catalogued as rs768883697; called by mutect2, varscan2
- OR2C3 | c.676G>A p.V226M | Missense Mutation (SNP) | VAF 56/143 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.186); catalogued as COSV63574846, COSV63576659; called by muse, mutect2, varscan2
- OR4C46 | c.872A>G p.Q291R | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.339); catalogued as COSV60218934; called by muse, mutect2, varscan2
- OR5AS1 | c.754T>C p.Y252H | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); catalogued as COSV57981528; called by muse, mutect2, varscan2
- ORC3 | c.56del p.K19Rfs*8 | Frame Shift Del (DEL) | VAF 173/516 reads (34%) | catalogued as rs1562313451; called by mutect2, pindel, varscan2
- OTX2 | c.98-4G>A | Splice Region (SNP) | VAF 17/36 reads (47%) | catalogued as rs780106127, COSV59765776; called by muse, mutect2, varscan2
- P4HA2 | c.1465C>A p.L489I | Missense Mutation (SNP) | VAF 101/253 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV51324531; called by muse, mutect2, varscan2
- PACS2 | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs374606643; called by muse, mutect2, varscan2
- PAGE5 | c.26G>A p.R9H | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.051); catalogued as rs769008290, COSV56943386; called by muse, mutect2, varscan2
- PANK4 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.127); catalogued as COSV101015637, COSV65830242; called by muse, mutect2
- PARD3 | c.3781A>G p.S1261G | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.977); catalogued as COSV61053894; called by muse, mutect2, varscan2
- PCBP2 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 82/202 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV63728447; called by muse, mutect2, varscan2
- PCDHA12 | c.1377G>C p.E459D | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.102); catalogued as COSV56493842, COSV56555620; called by muse, mutect2, varscan2
- PCDHB12 | c.773G>A p.G258D | Missense Mutation (SNP) | VAF 31/256 reads (12%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.433); catalogued as COSV53395436; called by muse, mutect2, varscan2
- PCDHB8 | c.1420G>A p.V474I | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.05); catalogued as rs782643110, COSV50762098; called by muse, mutect2, varscan2
- PCDHGC3 | c.1570C>G p.P524A | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV52749268, COSV52750789; called by muse, mutect2, varscan2
- PCNX3 | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 38/93 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.031); catalogued as COSV58419237; called by muse, mutect2, varscan2
- PCNX3 | c.2267G>T p.R756L | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.098); catalogued as COSV63136160, COSV63136175; called by mutect2, varscan2
- PCSK4 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.603); catalogued as COSV52013113; called by muse, mutect2, varscan2
- PDGFRL | c.798G>A p.A266= | Splice Region (SNP) | VAF 19/118 reads (16%) | catalogued as COSV52411808; called by muse, mutect2, varscan2
- PDLIM5 | c.563A>G p.D188G | Missense Mutation (SNP) | VAF 90/204 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV58747005; called by muse, mutect2, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 26/62 reads (42%) | catalogued as rs747131399; called by mutect2, varscan2
- PER2 | c.1958C>T p.S653L | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as rs1052237520, COSV54523004; called by muse, mutect2, varscan2
- PHACTR1 | c.1630C>T p.R544C | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs765398120, COSV60664451; called by muse, mutect2, varscan2
- PHB2 | c.554C>T p.T185I | Missense Mutation (SNP) | VAF 56/120 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54641685; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 13/33 reads (39%) | catalogued as rs769717544; called by mutect2, varscan2
- PIBF1 | c.33dup p.V12Sfs*5 | Frame Shift Ins (INS) | VAF 20/66 reads (30%) | catalogued as rs925772654; called by mutect2, varscan2
- PIK3CD | c.1033G>A p.A345T | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1423364986, COSV63128138; called by muse, mutect2, varscan2
- PIK3CG | c.58C>T p.R20C | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV63245266; called by muse, mutect2, varscan2
- PITX2 | c.668C>T p.S223L (on ENST00000354925 / NM_001204397.1; = p.S230L on NM_000325.6) | Missense Mutation (SNP) | VAF 83/189 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.107); catalogued as COSV60740732, COSV60741667; called by muse, mutect2, varscan2
- PKP2 | c.1511-1G>T p.X504_splice | Splice Site (SNP) | VAF 32/148 reads (22%) | catalogued as rs779082302, COSV50729050, COSV50731070; called by muse, mutect2, varscan2
- PLA2G7 | c.799del p.I267* | Frame Shift Del (DEL) | VAF 68/207 reads (33%) | catalogued as rs377632936; called by mutect2, pindel, varscan2
- PLCL2 | c.1106C>T p.A369V (on ENST00000615277 / NM_001144382.2; = p.A243V on NM_015184.5) | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.163); catalogued as COSV67621643; called by muse, mutect2
- PLEKHB1 | c.514T>C p.Y172H | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs377314135, COSV57049361; called by muse, mutect2, varscan2
- PLEKHG2 | c.1840G>A p.V614I | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.119); catalogued as rs147484241; called by muse, mutect2, varscan2
- PLEKHM2 | c.106C>T p.R36W | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs776184003, COSV65395890; called by muse, mutect2
- PLXNA2 | c.5627G>A p.R1876Q | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs778714938, COSV65439252; called by muse, mutect2
- PLXNA3 | c.2849del p.G950Afs*19 | Frame Shift Del (DEL) | VAF 25/82 reads (30%) | catalogued as COSV63753133; called by mutect2, pindel, varscan2
- PPP4R3A | c.1111-1G>T p.X371_splice | Splice Site (SNP) | VAF 9/212 reads (4%) | catalogued as rs1351021520, COSV61504214; called by muse, mutect2
- PRAG1 | c.2899G>T p.V967L | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as COSV58160002; called by muse, mutect2, varscan2
- PRAM1 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs1195075574, COSV55312034; called by muse, mutect2, varscan2
- PRDX2 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs147563022; called by muse, mutect2, varscan2
- PRICKLE1 | c.227T>C p.L76S | Missense Mutation (SNP) | VAF 110/280 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61542821; called by muse, mutect2, varscan2
- PRKAR1B | c.260del p.P87Rfs*5 | Frame Shift Del (DEL) | VAF 6/27 reads (22%) | catalogued as rs764069617; called by pindel, varscan2
- PRKCD | c.1300del p.D434Tfs*2 | Frame Shift Del (DEL) | VAF 36/93 reads (39%) | catalogued as rs1559629912, COSV57847601; called by mutect2, varscan2
- PRKCG | c.1220del p.G407Afs*27 | Frame Shift Del (DEL) | VAF 9/27 reads (33%) | catalogued as rs1324974599; called by mutect2, pindel, varscan2
- PRR11 | c.66del p.E23Kfs*9 | Frame Shift Del (DEL) | VAF 222/280 reads (79%) | catalogued as rs753236928; called by mutect2, varscan2
- PRR12 | c.37del p.H13Tfs*66 (on ENST00000615927; = p.P408Hfs*62 on NM_020719.3) | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | catalogued as rs763575972; called by mutect2, varscan2
- PRTG | c.3159del p.W1053Cfs*33 | Frame Shift Del (DEL) | VAF 27/99 reads (27%) | catalogued as COSV101221466, COSV66840045; called by mutect2, pindel, varscan2
- PTCH2 | c.3505del p.L1169Cfs*85 | Frame Shift Del (DEL) | VAF 32/77 reads (42%) | catalogued as rs763413121; called by mutect2, pindel, varscan2
- PTK2 | c.2906A>G p.D969G | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61784637; called by muse, mutect2, varscan2
- PTK2 | c.1421C>T p.T474I | Missense Mutation (SNP) | VAF 15/113 reads (13%) | SIFT tolerated (0.83); PolyPhen probably damaging (0.988); catalogued as COSV61784646; called by muse, mutect2, varscan2
- PUM1 | c.368G>C p.R123P | Missense Mutation (SNP) | VAF 148/392 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV57084134, COSV57091762; called by muse, mutect2, varscan2
- QSER1 | c.5090del p.N1697Mfs*4 (on ENST00000399302; = p.N1826Mfs*4 on NM_001076786.3) | Frame Shift Del (DEL) | VAF 44/120 reads (37%) | catalogued as rs754588466; called by mutect2, varscan2
- R3HDM2 | c.2737del p.D913Tfs*41 | Frame Shift Del (DEL) | VAF 9/78 reads (12%) | catalogued as COSV100234622; called by mutect2, pindel, varscan2
- RAB1A | c.220C>T p.R74* | Nonsense Mutation (SNP) | VAF 16/310 reads (5%) | catalogued as rs1374558705, COSV53124317; called by muse, mutect2
- RABGAP1 | c.2531G>A p.R844H | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); catalogued as COSV65379616; called by muse, mutect2, varscan2
- RAD18 | c.978dup p.T327Yfs*11 | Frame Shift Ins (INS) | VAF 121/371 reads (33%) | catalogued as rs34098429; called by mutect2, pindel, varscan2
- RASGRP2 | c.1579C>A p.L527I | Missense Mutation (SNP) | VAF 72/174 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as COSV62449247; called by muse, mutect2, varscan2
- RBM19 | c.1702A>G p.I568V | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs1483505423, COSV55690742; called by muse, mutect2, varscan2
- RBM45 | c.1149del p.A384Lfs*7 (on ENST00000616198 / NM_001365579.1; = p.A382Lfs*7 on NM_152945.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 32/88 reads (36%) | catalogued as rs749563266; called by mutect2, varscan2
- RBM6 | c.293dup p.D99Rfs*6 | Frame Shift Ins (INS) | VAF 53/150 reads (35%) | catalogued as rs764709206; called by mutect2, varscan2
- RBMX2 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 49/125 reads (39%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs1365230150, COSV59728690; called by muse, mutect2, varscan2
- RECK | c.2054dup p.N685Kfs*16 | Frame Shift Ins (INS) | VAF 77/222 reads (35%) | catalogued as rs935356864; called by mutect2, varscan2
- RELCH | c.1682A>G p.Q561R | Missense Mutation (SNP) | VAF 94/278 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.491); catalogued as COSV56884496; called by muse, mutect2, varscan2
- RELL1 | c.361G>A p.V121I | Missense Mutation (SNP) | VAF 97/226 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs776975272, COSV58451165; called by muse, mutect2, varscan2
- RFC3 | c.244del p.I82Lfs*25 | Frame Shift Del (DEL) | VAF 23/68 reads (34%) | catalogued as rs753959887; called by mutect2, varscan2
- RGS14 | c.1285A>G p.K429E | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.89); PolyPhen benign (0.005); catalogued as COSV68771105; called by muse, varscan2
- RGS9 | c.809G>A p.S270N | Missense Mutation (SNP) | VAF 57/186 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as COSV52224646; called by muse, mutect2, varscan2
- RMDN3 | c.1156del p.T386Lfs*22 | Frame Shift Del (DEL) | VAF 26/65 reads (40%) | catalogued as rs745408248; called by mutect2, varscan2
- RNF149 | c.566C>A p.T189N | Missense Mutation (SNP) | VAF 107/227 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.879); catalogued as COSV54863572; called by muse, mutect2, varscan2
- RNF212 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs766335413, COSV61364201; called by muse, mutect2, varscan2
- RNF41 | c.626C>T p.A209V | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61504271; called by muse, mutect2, varscan2
- RNF43 | c.1730del p.Q577Rfs*123 | Frame Shift Del (DEL) | VAF 18/69 reads (26%) | catalogued as COSV68459409; called by mutect2, pindel, varscan2
- RNF44 | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs776918972, COSV51269261; called by muse, mutect2, varscan2
- RPAP3 | c.226dup p.T76Nfs*14 | Frame Shift Ins (INS) | VAF 144/397 reads (36%) | catalogued as rs1326677198; called by mutect2, varscan2
- RPIA | c.794T>C p.V265A | Missense Mutation (SNP) | VAF 124/289 reads (43%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV52169028; called by muse, mutect2, varscan2
- RPUSD4 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.705); catalogued as COSV53599154; called by muse, mutect2, varscan2
- RSPH14 | c.956T>C p.M319T | Missense Mutation (SNP) | VAF 32/87 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs775881055, COSV53268032; called by muse, mutect2, varscan2
- SALL3 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV73305960; called by muse, mutect2
- SALL4 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs1313487388, COSV53851550; called by muse, mutect2, varscan2
- SAMD4B | c.1756G>A p.G586S | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs768979433, COSV58751152; called by muse, mutect2
- SART3 | c.1922G>A p.R641H (on ENST00000228284; = p.R623H on NM_014706.4) | Missense Mutation (SNP) | VAF 260/615 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as rs368454974; called by muse, mutect2, varscan2
- SATB1 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 102/226 reads (45%) | catalogued as COSV58668666; called by muse, mutect2, varscan2
- SCAF4 | c.749del p.P250Hfs*96 | Frame Shift Del (DEL) | VAF 201/593 reads (34%) | catalogued as COSV54589079; called by mutect2, pindel, varscan2
- SEC31B | c.3109C>A p.Q1037K | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT tolerated (0.74); PolyPhen benign (0.033); catalogued as COSV64844172; called by muse, mutect2, varscan2
- SEC62 | c.429del p.D144Mfs*58 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | catalogued as rs751191303; called by mutect2, varscan2
- SEH1L | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 126/309 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50816590; called by muse, mutect2, varscan2
- SEMA3D | c.1453G>A p.E485K | Missense Mutation (SNP) | VAF 72/195 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.485); catalogued as COSV52391580; called by muse, mutect2, varscan2
- SEMA4A | c.1087C>T p.R363C | Missense Mutation (SNP) | VAF 81/197 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs750520474, COSV61772232; called by muse, mutect2, varscan2
- SENP2 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 72/184 reads (39%) | SIFT tolerated (0.33); PolyPhen benign (0.044); catalogued as rs567119131, COSV56192368; called by muse, mutect2, varscan2
- SENP2 | c.1088A>G p.D363G | Missense Mutation (SNP) | VAF 85/217 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as rs1423338340, COSV56193902; called by muse, mutect2, varscan2
- SENP7 | c.1635del p.K545Nfs*11 | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | catalogued as rs764980440, COSV58616367; called by mutect2, pindel, varscan2
- SERAC1 | c.467C>T p.S156L | Missense Mutation (SNP) | VAF 92/191 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.054); catalogued as rs528155939, COSV65596304; called by muse, mutect2, varscan2
- SFSWAP | c.1229C>T p.T410I | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV55519284; called by muse, mutect2, varscan2
- SGO2 | c.3191_3193del p.E1064del | In Frame Del (DEL) | VAF 19/56 reads (34%) | catalogued as rs756243045; called by pindel, varscan2
- SHANK3 | c.2306G>A p.G769E | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53185664; called by muse, mutect2
- SHC1 | c.517C>A p.L173I (on ENST00000368445 / NM_183001.5; = p.L63I on NM_003029.5) | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63534762; called by muse, mutect2, varscan2
- SHFL | c.566del p.P189Rfs*67 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as COSV53462966; called by mutect2, varscan2
- SIGLEC1 | c.4007G>A p.R1336H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); catalogued as rs199713985; called by muse, mutect2
- SIGLEC10 | c.1488del p.S497Afs*11 | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as rs771159868, COSV59487155; called by mutect2, pindel, varscan2
- SIGLEC11 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 30/159 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.109); catalogued as rs748192530, COSV70221956; called by muse, mutect2, varscan2
- SKOR1 | c.802A>G p.K268E | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58245250; called by muse, mutect2, varscan2
- SLC19A3 | c.1093T>C p.Y365H | Missense Mutation (SNP) | VAF 46/114 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.852); catalogued as COSV51452362; called by muse, mutect2, varscan2
- SLC22A1 | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1441577213, CM156723, COSV61452116; called by muse, mutect2, varscan2
- SLC26A9 | c.25G>A p.V9M | Missense Mutation (SNP) | VAF 108/263 reads (41%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.539); catalogued as rs369903387; called by muse, mutect2, varscan2
- SLC30A9 | c.581G>A p.R194H | Missense Mutation (SNP) | VAF 57/190 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs144935504; called by muse, mutect2, varscan2
- SLC35C2 | c.631G>A p.G211R | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV54756646; called by muse, mutect2, varscan2
- SLC38A5 | c.986G>A p.S329N | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.035); catalogued as COSV58333984; called by muse, mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 50/131 reads (38%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC44A4 | c.1612A>G p.M538V | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs757523398, COSV57666870; called by muse, mutect2, varscan2
- SLC45A2 | c.895A>G p.R299G | Missense Mutation (SNP) | VAF 64/185 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV56871137; called by muse, mutect2, varscan2
- SLC4A11 | c.2243T>C p.I748T | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.683); catalogued as COSV66261473; called by muse, mutect2, varscan2
- SLC5A4 | c.853A>G p.I285V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.03); catalogued as COSV56669724; called by muse, mutect2, varscan2
- SLC6A14 | c.1749A>G p.I583M | Missense Mutation (SNP) | VAF 182/437 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV64140960; called by muse, mutect2, varscan2
- SLC9B2 | c.700G>A p.G234R | Missense Mutation (SNP) | VAF 52/173 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV60018728; called by muse, mutect2, varscan2
- SLK | c.2839C>T p.R947C | Missense Mutation (SNP) | VAF 51/178 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); catalogued as rs373815490, COSV59823849; called by muse, mutect2, varscan2
- SMAD1 | c.430A>G p.S144G | Missense Mutation (SNP) | VAF 116/276 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as COSV57470904; called by muse, mutect2, varscan2
- SMAP1 | c.613del p.S205Vfs*15 (on ENST00000370455 / NM_001044305.3; = p.S178Vfs*15 on NM_021940.5) | Frame Shift Del (DEL) | VAF 52/140 reads (37%) | catalogued as rs766085867, COSV100391091; called by mutect2, pindel, varscan2
- SMC1A | c.1910A>G p.K637R | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.291); catalogued as COSV104398805, COSV59128784; called by muse, mutect2, varscan2
- SMTN | c.812A>G p.E271G | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV60777388; called by muse, varscan2
- SNAI2 | c.523A>G p.K175E | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50078898; called by muse, mutect2, varscan2
- SNAPC1 | c.639dup p.D214* | Frame Shift Ins (INS) | VAF 30/228 reads (13%) | catalogued as rs778933382; called by mutect2, varscan2
- SPATA18 | c.152A>G p.Q51R | Missense Mutation (SNP) | VAF 9/145 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54643719; called by muse, mutect2
- SPEG | c.6697del p.Q2233Rfs*6 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | catalogued as rs752907815; called by mutect2, pindel, varscan2
- SPTA1 | c.3422C>A p.A1141D | Missense Mutation (SNP) | VAF 109/278 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63751799; called by muse, mutect2, varscan2
- SRPX | c.878G>A p.G293D | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59438124; called by muse, mutect2, varscan2
- SSH2 | c.2171A>G p.E724G | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV52170850; called by muse, mutect2
- STPG1 | c.901C>G p.P301A (on ENST00000337248 / NM_001199013.2; = p.P254A on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/65 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV50218610; called by muse, mutect2, varscan2
- SYNJ1 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370189840; called by muse, mutect2, varscan2
- TBPL2 | c.608+2T>C p.X203_splice | Splice Site (SNP) | VAF 41/177 reads (23%) | catalogued as COSV55972345; called by muse, mutect2, varscan2
- TBX15 | c.1625T>C p.L542S (on ENST00000369429 / NM_001330677.2; = p.L436S on NM_152380.3) | Missense Mutation (SNP) | VAF 113/241 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV52870123; called by muse, mutect2, varscan2
- TBX21 | c.1269G>T p.Q423H | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.275); catalogued as COSV51595755; called by muse, mutect2, varscan2
- TEAD2 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 67/190 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55562105; called by mutect2, varscan2
- TENM1 | c.5881C>T p.H1961Y | Missense Mutation (SNP) | VAF 97/234 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64430067; called by muse, mutect2, varscan2
- TENM1 | c.2207G>A p.C736Y | Missense Mutation (SNP) | VAF 92/246 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64430074; called by muse, mutect2, varscan2
- TENM3 | c.3304C>T p.Q1102* | Nonsense Mutation (SNP) | VAF 112/321 reads (35%) | catalogued as COSV69305089; called by muse, mutect2, varscan2
- TEX15 | c.4143del p.E1382Sfs*3 (on ENST00000256246; = p.E1765Sfs*3 on NM_001350162.2) | Frame Shift Del (DEL) | VAF 45/132 reads (34%) | catalogued as COSV56351976; called by mutect2, pindel, varscan2
- TFAM | c.441del p.E148Sfs*2 | Frame Shift Del (DEL) | VAF 38/85 reads (45%) | catalogued as rs544132101; called by mutect2, varscan2
- TFAP2B | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs761528653, COSV53826979; called by muse, mutect2, varscan2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 22/68 reads (32%) | catalogued as rs782753958; called by mutect2, varscan2
- TGM4 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 75/177 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56093557; called by muse, mutect2, varscan2
- THBS3 | c.793G>C p.E265Q | Missense Mutation (SNP) | VAF 51/156 reads (33%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as COSV64249041; called by muse, mutect2, varscan2
- TIGD3 | c.1225A>G p.K409E | Missense Mutation (SNP) | VAF 49/120 reads (41%) | SIFT tolerated (0.37); PolyPhen benign (0.026); catalogued as COSV52888924; called by muse, mutect2, varscan2
- TJP3 | c.1807C>A p.R603S | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV53662018; called by muse, mutect2, varscan2
- TMEM181 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 22/127 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.25); catalogued as rs188259608, COSV65562904; called by muse, mutect2, varscan2
- TMEM260 | c.1102G>A p.A368T | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as rs1428571512, COSV55098330; called by muse, mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 58/132 reads (44%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNMD | c.642del p.I216Lfs*12 | Frame Shift Del (DEL) | VAF 100/234 reads (43%) | catalogued as rs754014575; called by mutect2, varscan2
- TNRC6A | c.2936C>T p.A979V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs746176011, COSV59363158; called by muse, mutect2, varscan2
- TPH2 | c.1412G>A p.R471H | Missense Mutation (SNP) | VAF 116/267 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs138642957; called by muse, mutect2, varscan2
- TPO | c.1666A>G p.M556V | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.068); catalogued as COSV61099792; called by muse, mutect2, varscan2
- TRAF1 | c.537G>T p.Q179H | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV65868224; called by muse, mutect2, varscan2
- TRIM38 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as rs375143343; called by muse, mutect2, varscan2
- TRPC3 | c.314G>A p.R105H (on ENST00000379645 / NM_001366479.2; = p.R32H on NM_003305.2) | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); catalogued as rs200623780; called by muse, mutect2
- TRPM3 | c.3337A>G p.I1113V (on ENST00000357533 / NM_001366142.2; = p.I968V on NM_020952.6) | Missense Mutation (SNP) | VAF 46/123 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV62584409; called by muse, mutect2, varscan2
- TSHZ2 | c.614G>A p.C205Y | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61588233; called by muse, mutect2, varscan2
- TSHZ3 | c.2719C>A p.Q907K | Missense Mutation (SNP) | VAF 34/80 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV53669169; called by muse, mutect2, varscan2
- TSPYL1 | c.1115A>G p.D372G | Missense Mutation (SNP) | VAF 26/203 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.173); catalogued as COSV63994032; called by muse, mutect2, varscan2
- TSSK1B | c.583A>G p.K195E | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as COSV66815190; called by muse, mutect2, varscan2
- TTF2 | c.732T>G p.S244R | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV65632400; called by muse, mutect2, varscan2
- TTK | c.2560A>G p.R854G | Missense Mutation (SNP) | VAF 60/122 reads (49%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs755816263, COSV57881176, COSV57881188; called by muse, varscan2
- TTN | c.5296G>A p.V1766I (on ENST00000591111; = p.V1720I on NM_003319.4) | Missense Mutation (SNP) | VAF 31/73 reads (42%) | PolyPhen benign (0.012); catalogued as rs149494502; ClinVar: likely benign; called by muse, mutect2, varscan2
- TUFT1 | c.48G>T p.E16D | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.159); catalogued as COSV54969369; called by muse, mutect2, varscan2
- UBA6 | c.2588C>G p.T863R | Missense Mutation (SNP) | VAF 56/292 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs766320178, COSV59176313; called by muse, mutect2, varscan2
- UMOD | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56775073; called by muse, mutect2, varscan2
- UQCRC1 | c.1414C>T p.R472C | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs778390581, COSV52551435; called by muse, mutect2, varscan2
- USF2 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770157891, COSV55886832; called by muse, mutect2, varscan2
- USP35 | c.1059del p.M354Wfs*119 | Frame Shift Del (DEL) | VAF 22/85 reads (26%) | catalogued as rs761345427; called by mutect2, pindel, varscan2
- USP48 | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 82/201 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.521); catalogued as rs1330400093, COSV57609060; called by muse, mutect2, varscan2
- VASH2 | c.362T>C p.L121P | Missense Mutation (SNP) | VAF 92/244 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55117491; called by muse, mutect2, varscan2
- VWA5A | c.890G>A p.S297N | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT tolerated (0.75); PolyPhen benign (0.012); catalogued as COSV63707522; called by muse, mutect2, varscan2
- VWCE | c.886C>A p.L296M | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.606); catalogued as COSV57111877; called by muse, mutect2, varscan2
- WAC | c.554G>T p.R185M | Missense Mutation (SNP) | VAF 77/192 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.027); catalogued as COSV61567392; called by muse, mutect2, varscan2
- WDFY2 | c.1195G>A p.V399M | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.971); catalogued as rs746582417, COSV53288647; called by muse, mutect2, varscan2
- WDR37 | c.407G>A p.S136N | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as COSV54128247, COSV54128784; called by muse, mutect2, varscan2
- WEE2 | c.1234C>T p.L412F | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66878659; called by muse, mutect2, varscan2
- WNK4 | c.1822del p.V608Cfs*53 | Frame Shift Del (DEL) | VAF 6/14 reads (43%) | catalogued as rs762079039; called by mutect2, varscan2
- WNT5B | c.425G>A p.G142D | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV60197762; called by muse, varscan2
- YTHDF1 | c.1505T>C p.V502A | Missense Mutation (SNP) | VAF 59/329 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV64832792; called by muse, mutect2, varscan2
- ZBTB24 | c.501del p.V168Sfs*19 | Frame Shift Del (DEL) | VAF 117/362 reads (32%) | catalogued as rs780371205; called by mutect2, pindel, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 82/183 reads (45%) | catalogued as rs745875253; called by mutect2, varscan2
- ZFAT | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.887); catalogued as rs780842427, COSV64737203; called by muse, mutect2, varscan2
- ZFHX3 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51715367; called by muse, mutect2, varscan2
- ZMIZ2 | c.1609G>A p.V537M | Missense Mutation (SNP) | VAF 57/115 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as rs779329650, COSV54807257; called by muse, mutect2, varscan2
- ZMYM2 | c.3131del p.K1044Rfs*33 | Frame Shift Del (DEL) | VAF 144/308 reads (47%) | catalogued as rs753611080; called by mutect2, varscan2
- ZMYM4 | c.1290del p.K430Nfs*6 | Frame Shift Del (DEL) | VAF 88/236 reads (37%) | catalogued as rs755663477, COSV58913572; called by mutect2, varscan2
- ZNF197 | c.1930C>T p.H644Y | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60360356; called by muse, mutect2, varscan2
- ZNF248 | c.806C>T p.P269L | Missense Mutation (SNP) | VAF 58/133 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as rs199680671, COSV61997499; called by muse, mutect2, varscan2
- ZNF318 | c.6394G>T p.G2132* | Nonsense Mutation (SNP) | VAF 61/137 reads (45%) | catalogued as COSV58931811; called by muse, mutect2, varscan2
- ZNF333 | c.1505G>A p.R502K | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT tolerated (0.96); PolyPhen possibly damaging (0.655); catalogued as COSV52885636; called by muse, mutect2, varscan2
- ZNF438 | c.211A>G p.K71E | Missense Mutation (SNP) | VAF 110/276 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV59194208, COSV59201343; called by muse, mutect2, varscan2
- ZNF462 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 111/261 reads (43%) | catalogued as COSV52935648; called by muse, mutect2, varscan2
- ZNF513 | c.463T>C p.C155R | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52007371; called by muse, mutect2, varscan2
- ZNF532 | c.3458G>T p.R1153M | Missense Mutation (SNP) | VAF 72/177 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.302); catalogued as COSV60172488, COSV60172653; called by muse, mutect2, varscan2
- ZNF611 | c.677T>C p.M226T | Missense Mutation (SNP) | VAF 164/395 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60540461; called by muse, mutect2, varscan2
- ZNF680 | c.766C>A p.H256N | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59014986; called by muse, mutect2, varscan2
- ZNF81 | c.1736A>G p.E579G | Missense Mutation (SNP) | VAF 75/176 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV58575814; called by muse, mutect2, varscan2
- ZNF862 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 42/111 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs1250874190, COSV56222639; called by muse, mutect2, varscan2
- ZRANB1 | c.1772C>T p.A591V | Missense Mutation (SNP) | VAF 11/398 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.193); catalogued as COSV61471638; called by muse, mutect2
- ZRANB1 | c.*9del | Frame Shift Del (DEL) | VAF 26/70 reads (37%) | catalogued as rs535580590; called by mutect2, varscan2
- ZRSR2 | c.910G>A p.V304M | Missense Mutation (SNP) | VAF 62/294 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57063909; called by muse, mutect2, varscan2
- ZSWIM8 | c.5085del p.Y1696Tfs*17 (on ENST00000605216 / NM_001242487.2; = p.Y1701Tfs*17 on NM_015037.3) | Frame Shift Del (DEL) | VAF 90/186 reads (48%) | catalogued as rs769663113; called by mutect2, varscan2
- ZXDC | c.1525A>G p.M509V | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV60446671; called by muse, mutect2, varscan2
- ZYX | c.1144G>T p.E382* | Nonsense Mutation (SNP) | VAF 15/46 reads (33%) | catalogued as COSV51968700, COSV51970494; called by muse, mutect2, varscan2
- ADCY8 | c.1768_1778del p.P590Sfs*6 | Frame Shift Del (DEL) | VAF 40/107 reads (37%) | called by mutect2, pindel, varscan2
- AFG3L2 | c.255del p.A86Lfs*99 | Frame Shift Del (DEL) | VAF 111/339 reads (33%) | called by mutect2, pindel, varscan2
- AGPAT3 | c.348+1del | Frame Shift Del (DEL) | VAF 45/121 reads (37%) | called by mutect2, pindel, varscan2
- ALG13 | c.3291del p.W1098Gfs*18 | Frame Shift Del (DEL) | VAF 39/314 reads (12%) | called by mutect2, pindel, varscan2
- AMOTL2 | c.2201del p.P734Qfs*30 (on ENST00000422605; = p.P735Qfs*30 on NM_016201.4) | Frame Shift Del (DEL) | VAF 16/53 reads (30%) | called by mutect2, pindel, varscan2
- ARHGAP30 | c.1418del p.P473Qfs*41 | Frame Shift Del (DEL) | VAF 17/38 reads (45%) | called by mutect2, pindel, varscan2
- ARHGEF17 | c.1850del p.P617Lfs*10 | Frame Shift Del (DEL) | VAF 24/77 reads (31%) | called by mutect2, pindel, varscan2
- ARID1A | c.4555del p.Q1519Rfs*8 | Frame Shift Del (DEL) | VAF 12/80 reads (15%) | called by pindel, varscan2
- ARID1A | c.4563del p.A1522Pfs*5 | Frame Shift Del (DEL) | VAF 29/89 reads (33%) | called by pindel, varscan2
- ASAP2 | c.2795del p.P932Lfs*13 | Frame Shift Del (DEL) | VAF 78/241 reads (32%) | called by mutect2, pindel, varscan2
- ASB3 | c.817del p.A273Pfs*6 | Frame Shift Del (DEL) | VAF 26/133 reads (20%) | called by mutect2, pindel, varscan2
- BCAR1 | c.1244del p.P415Qfs*56 | Frame Shift Del (DEL) | VAF 18/36 reads (50%) | called by mutect2, pindel, varscan2
- C12orf29 | c.313del p.W105Gfs*23 | Frame Shift Del (DEL) | VAF 36/86 reads (42%) | called by mutect2, pindel, varscan2
- CASP8AP2 | c.3707del p.N1236Ifs*9 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | called by mutect2, varscan2
- CBX5 | c.317dup p.R107Efs*6 | Frame Shift Ins (INS) | VAF 92/253 reads (36%) | called by mutect2, varscan2
- CCL4 | c.101G>T p.C34F | Missense Mutation (SNP) | VAF 118/337 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CEP55 | c.738del p.D247Ifs*9 | Frame Shift Del (DEL) | VAF 52/165 reads (32%) | called by mutect2, pindel, varscan2
- CHD3 | c.1618del p.R540Vfs*16 | Frame Shift Del (DEL) | VAF 44/117 reads (38%) | called by mutect2, pindel, varscan2
- CNTNAP2 | c.2496del p.W833Gfs*18 | Frame Shift Del (DEL) | VAF 120/318 reads (38%) | called by mutect2, pindel, varscan2
- DLST | c.812dup p.L271Ffs*5 | Frame Shift Ins (INS) | VAF 66/222 reads (30%) | called by mutect2, pindel, varscan2
- DNMBP | c.582del p.P195Qfs*5 | Frame Shift Del (DEL) | VAF 27/96 reads (28%) | called by mutect2, pindel, varscan2
- FAM200A | c.1053del p.F351Lfs*7 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | called by pindel, varscan2
- FAT2 | c.10920del p.E3641Rfs*4 | Frame Shift Del (DEL) | VAF 8/19 reads (42%) | called by mutect2, varscan2
- FECH | c.978del p.R327Gfs*9 | Frame Shift Del (DEL) | VAF 37/233 reads (16%) | called by mutect2, pindel, varscan2
- FEZ2 | c.842dup p.K282Efs*13 | Frame Shift Ins (INS) | VAF 36/220 reads (16%) | called by mutect2, pindel, varscan2
- FOXM1 | c.2008del p.E671Nfs*12 | Frame Shift Del (DEL) | VAF 40/105 reads (38%) | called by mutect2, pindel, varscan2
- GABRB3 | c.508del p.L170Wfs*66 | Frame Shift Del (DEL) | VAF 128/400 reads (32%) | called by pindel, varscan2
- GPR179 | c.4173G>T p.E1391D (on ENST00000621958; = p.E1390D on NM_001004334.4) | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GRID1 | c.2019dup p.Q674Tfs*16 | Frame Shift Ins (INS) | VAF 45/146 reads (31%) | called by mutect2, pindel, varscan2
- HMGCR | c.1229del p.P410Qfs*21 | Frame Shift Del (DEL) | VAF 87/267 reads (33%) | called by mutect2, pindel, varscan2
- HOOK1 | c.737dup p.Y247Vfs*19 | Frame Shift Ins (INS) | VAF 81/233 reads (35%) | called by mutect2, pindel, varscan2
- HOXA3 | c.813del p.G272Efs*6 | Frame Shift Del (DEL) | VAF 35/109 reads (32%) | called by mutect2, pindel, varscan2
- IFIH1 | c.1403del p.N468Tfs*11 | Frame Shift Del (DEL) | VAF 127/409 reads (31%) | called by mutect2, pindel, varscan2
- IL7R | c.361del p.I121* | Frame Shift Del (DEL) | VAF 86/234 reads (37%) | called by mutect2, pindel, varscan2
- INPP5D | c.1576del p.V526Cfs*10 (on ENST00000445964 / NM_001017915.3; = p.V525Cfs*10 on NM_005541.5) | Frame Shift Del (DEL) | VAF 93/273 reads (34%) | called by mutect2, pindel, varscan2
- INTS14 | c.1171del p.L391Cfs*13 (on ENST00000313182 / NM_001366360.2; = p.L312Cfs*13 on NM_001136043.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 116/355 reads (33%) | called by mutect2, pindel, varscan2
- ITGA10 | c.1052_1054del p.G351del | In Frame Del (DEL) | VAF 87/235 reads (37%) | called by mutect2, pindel, varscan2
- JAK1 | c.1035dup p.L346Tfs*4 | Frame Shift Ins (INS) | VAF 172/498 reads (35%) | called by mutect2, pindel, varscan2
- KCNAB2 | c.970dup p.A324Gfs*29 | Frame Shift Ins (INS) | VAF 43/111 reads (39%) | called by mutect2, pindel, varscan2
- KCNB1 | c.2206del p.R736Gfs*9 | Frame Shift Del (DEL) | VAF 26/116 reads (22%) | called by mutect2, varscan2
- KCTD15 | c.139del p.L47Cfs*36 | Frame Shift Del (DEL) | VAF 54/122 reads (44%) | called by mutect2, pindel, varscan2
- KIF5C | c.310del p.Q104Sfs*28 | Frame Shift Del (DEL) | VAF 26/100 reads (26%) | called by mutect2, pindel, varscan2
- LMBR1 | c.346dup p.S116Ffs*58 | Frame Shift Ins (INS) | VAF 91/260 reads (35%) | called by mutect2, pindel, varscan2
- LRPPRC | c.3147_3148+31delinsGGCAAGCACATACGGGGATGGGGGTGTGTGT p.X1049_splice | Splice Site (DEL) | VAF 67/398 reads (17%) | called by pindel, varscan2*
- LRRC30 | c.897del p.K299Nfs*? | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- LSG1 | c.1938del p.E647Kfs*43 | Frame Shift Del (DEL) | VAF 59/166 reads (36%) | called by mutect2, pindel, varscan2
- LTBP1 | c.1794dup p.K599Qfs*19 (on ENST00000404816 / NM_206943.4; = p.K273Qfs*19 on NM_000627.4) | Frame Shift Ins (INS) | VAF 26/165 reads (16%) | called by mutect2, pindel, varscan2
- LTBR | c.543del p.S182Afs*33 | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | called by mutect2, pindel, varscan2
- MAGEB16 | c.395del p.K132Sfs*3 | Frame Shift Del (DEL) | VAF 63/170 reads (37%) | called by mutect2, pindel, varscan2
- MAGEB3 | c.121del p.S41Hfs*35 | Frame Shift Del (DEL) | VAF 24/69 reads (35%) | called by mutect2, pindel, varscan2
- MSANTD4 | c.544del p.H182Tfs*24 | Frame Shift Del (DEL) | VAF 64/200 reads (32%) | called by mutect2, pindel, varscan2
- MYF6 | c.222del p.G75Afs*4 | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | called by mutect2, pindel, varscan2
- MYO18A | c.627dup p.V210Rfs*49 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | called by mutect2, pindel, varscan2
- MYO1C | c.636del p.V213Wfs*56 (on ENST00000648651 / NM_001080779.2; = p.V178Wfs*56 on NM_033375.5) | Frame Shift Del (DEL) | VAF 38/102 reads (37%) | called by mutect2, varscan2
- NCOR1 | c.1573dup p.T525Nfs*11 | Frame Shift Ins (INS) | VAF 56/171 reads (33%) | called by mutect2, pindel, varscan2
- NIPBL | c.1697del p.K566Sfs*48 | Frame Shift Del (DEL) | VAF 41/121 reads (34%) | called by mutect2, pindel, varscan2
- NKAPD1 | c.479del p.K160Sfs*20 (on ENST00000280352 / NM_001082970.2; = p.K161Sfs*20 on NM_018195.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 46/234 reads (20%) | called by mutect2, varscan2
- NRIP1 | c.1547dup p.N516Kfs*10 | Frame Shift Ins (INS) | VAF 158/403 reads (39%) | called by mutect2, varscan2
- PHC1 | c.1560A>T p.Q520H | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.648); called by mutect2, varscan2
- POLQ | c.4289del p.L1430* | Frame Shift Del (DEL) | VAF 26/77 reads (34%) | called by mutect2, pindel, varscan2
- PPP1R36 | c.500del p.N167Tfs*12 | Frame Shift Del (DEL) | VAF 73/219 reads (33%) | called by mutect2, pindel, varscan2
- PRELP | c.242del p.P81Lfs*61 | Frame Shift Del (DEL) | VAF 78/270 reads (29%) | called by mutect2, pindel, varscan2
- PRKAR1B | c.197del p.L66Wfs*26 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by pindel, varscan2
- PUS7 | c.96del p.K32Nfs*9 | Frame Shift Del (DEL) | VAF 164/476 reads (34%) | called by mutect2, pindel, varscan2
- RANBP2 | c.3074_3075del p.T1025Nfs*7 | Frame Shift Del (DEL) | VAF 66/228 reads (29%) | called by pindel, varscan2
- RANBP2 | c.3724dup p.I1242Nfs*29 | Frame Shift Ins (INS) | VAF 12/96 reads (13%) | called by mutect2, pindel, varscan2
- RBP3 | c.3246-2A>G p.X1082_splice | Splice Site (SNP) | VAF 64/172 reads (37%) | called by muse, mutect2, varscan2
- RHOC | c.217_218del p.S73Lfs*5 | Frame Shift Del (DEL) | VAF 26/80 reads (33%) | called by pindel, varscan2
- RIF1 | c.767_770del p.F256Sfs*21 | Frame Shift Del (DEL) | VAF 44/163 reads (27%) | called by pindel, varscan2
- RRN3 | c.1793del p.K598Rfs*3 | Frame Shift Del (DEL) | VAF 40/230 reads (17%) | called by mutect2, pindel, varscan2
- SAFB | c.2399del p.G800Afs*8 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | called by mutect2, pindel, varscan2
- SH3RF1 | c.869dup p.H292Afs*145 | Frame Shift Ins (INS) | VAF 150/460 reads (33%) | called by mutect2, pindel, varscan2
- SLC34A3 | c.794dup p.N265Kfs*4 | Frame Shift Ins (INS) | VAF 9/27 reads (33%) | called by mutect2, pindel, varscan2
- SOWAHB | c.985T>G p.S329A | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.223); called by muse, mutect2
- STIMATE | c.215del p.L72* | Frame Shift Del (DEL) | VAF 56/194 reads (29%) | called by pindel, varscan2
- TAGLN2 | c.341_342del p.V114Gfs*27 | Frame Shift Del (DEL) | VAF 30/96 reads (31%) | called by pindel, varscan2
- THEMIS2 | c.1652del p.P551Hfs*28 | Frame Shift Del (DEL) | VAF 17/59 reads (29%) | called by mutect2, pindel, varscan2
- TJP1 | c.1694del p.N565Ifs*5 | Frame Shift Del (DEL) | VAF 140/355 reads (39%) | called by mutect2, pindel, varscan2
- TMC8 | c.422del p.P141Lfs*7 | Frame Shift Del (DEL) | VAF 21/50 reads (42%) | called by mutect2, pindel, varscan2
- TPD52L3 | c.175dup p.E59Gfs*24 | Frame Shift Ins (INS) | VAF 49/132 reads (37%) | called by mutect2, pindel, varscan2
- TSPYL2 | c.552_554del p.R184del | In Frame Del (DEL) | VAF 16/70 reads (23%) | called by pindel, varscan2
- TTK | c.575del p.K192Sfs*18 | Frame Shift Del (DEL) | VAF 57/143 reads (40%) | called by mutect2, pindel, varscan2
- TXNDC11 | c.1479dup p.E494* (on ENST00000356957 / NM_001303447.2; = p.E467* on NM_015914.7 and 3 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- UBQLN4 | c.426dup p.P143Afs*52 | Frame Shift Ins (INS) | VAF 22/73 reads (30%) | called by mutect2, pindel, varscan2
- UBR5 | c.8231_8233del p.E2744del | In Frame Del (DEL) | VAF 96/292 reads (33%) | called by pindel, varscan2
- UNK | c.873del p.E292Rfs*28 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- ZBTB4 | c.42del p.A15Pfs*21 | Frame Shift Del (DEL) | VAF 15/54 reads (28%) | called by mutect2, pindel, varscan2
- ZC3H12B | c.2071del p.Q691Sfs*7 | Frame Shift Del (DEL) | VAF 39/103 reads (38%) | called by mutect2, pindel, varscan2
- ZDHHC8 | c.1049del p.P350Rfs*33 | Frame Shift Del (DEL) | VAF 28/73 reads (38%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.2379del p.S794Rfs*30 | Frame Shift Del (DEL) | VAF 32/81 reads (40%) | called by mutect2, pindel, varscan2
- ZMYM6 | c.292del p.M98Cfs*49 | Frame Shift Del (DEL) | VAF 52/315 reads (17%) | called by mutect2, pindel, varscan2
- ZNF22 | c.602del p.N201Ifs*4 | Frame Shift Del (DEL) | VAF 17/96 reads (18%) | called by mutect2, pindel, varscan2
- ZNF800 | c.207del p.F69Lfs*16 | Frame Shift Del (DEL) | VAF 62/190 reads (33%) | called by mutect2, pindel, varscan2
- ZSWIM8 | c.2438del p.P813Lfs*22 | Frame Shift Del (DEL) | VAF 14/35 reads (40%) | called by mutect2, pindel, varscan2
- ZSWIM8 | c.4010del p.P1337Lfs*19 (on ENST00000605216 / NM_001242487.2; = p.P1342Lfs*19 on NM_015037.3) | Frame Shift Del (DEL) | VAF 33/99 reads (33%) | called by mutect2, pindel, varscan2
- ABCC10 | c.1095C>T p.C365= (on ENST00000372530 / NM_001198934.2; = p.C322= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/69 reads (43%) | catalogued as COSV55086713; called by muse, mutect2, varscan2
- ACKR3 | c.885G>A p.T295= | Silent (SNP) | VAF 45/103 reads (44%) | catalogued as rs781583037, COSV56021318; called by muse, mutect2, varscan2
- ADAMTS20 | c.801T>C p.A267= | Silent (SNP) | VAF 145/390 reads (37%) | catalogued as COSV67130163; called by muse, mutect2, varscan2
- AFTPH | c.1134T>C p.D378= | Silent (SNP) | VAF 28/161 reads (17%) | catalogued as rs1004223598, COSV53217301; called by muse, mutect2, varscan2
- ANKRD17 | c.2665C>T p.L889= | Silent (SNP) | VAF 17/539 reads (3%) | catalogued as COSV58218759; called by muse, mutect2
- AR | c.1761C>T p.A587= | Silent (SNP) | VAF 93/222 reads (42%) | catalogued as rs756485947, COSV65955380, COSV65963877; called by muse, mutect2, varscan2
- ARRDC5 | c.855C>T p.D285= (on ENST00000381781; = p.D271= on NM_001080523.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/128 reads (48%) | catalogued as rs777901315, COSV67787879; called by muse, mutect2, varscan2
- ASTN1 | c.2115C>A p.T705= | Silent (SNP) | VAF 8/98 reads (8%) | catalogued as COSV56066628; called by muse, mutect2
- ASXL3 | c.5682C>G p.V1894= | Silent (SNP) | VAF 38/117 reads (32%) | catalogued as COSV52463450; called by muse, mutect2, varscan2
- ATN1 | c.3271C>A p.R1091= | Silent (SNP) | VAF 72/312 reads (23%) | catalogued as rs782540066, COSV57546691, COSV99980710; called by muse, mutect2, varscan2
- B4GALNT4 | c.954G>A p.L318= | Silent (SNP) | VAF 7/24 reads (29%) | catalogued as COSV57322820; called by muse, mutect2, varscan2
- BAIAP3 | c.3441G>A p.L1147= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV50103886; called by muse, mutect2, varscan2
- BCOR | c.4050C>T p.Y1350= (on ENST00000378444 / NM_001123385.2; = p.Y1316= on NM_017745.6) | Silent (SNP) | VAF 159/334 reads (48%) | catalogued as COSV60699961, COSV60705362; called by muse, mutect2, varscan2
- BCORL1 | c.714A>G p.P238= | Silent (SNP) | VAF 85/248 reads (34%) | catalogued as COSV54394563; called by muse, mutect2, varscan2
- C16orf89 | c.792C>T p.S264= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as rs768695208, COSV60123281; called by muse, mutect2, varscan2
- C17orf98 | c.132C>T p.N44= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as rs373474691; called by muse, mutect2, varscan2
- CCDC151 | c.1602C>T p.S534= | Silent (SNP) | VAF 78/202 reads (39%) | catalogued as rs763966178, COSV62697683; called by muse, mutect2, varscan2
- CD248 | c.969G>A p.Q323= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as COSV60936250; called by muse, mutect2, varscan2
- CDH1 | c.375C>A p.P125= | Silent (SNP) | VAF 15/127 reads (12%) | catalogued as rs773044699, COSV55730988; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDH3 | c.1290C>T p.H430= | Silent (SNP) | VAF 48/120 reads (40%) | catalogued as rs1223690532, COSV50556572; called by muse, mutect2, varscan2
- CELSR1 | c.1623G>C p.R541= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV53088005, COSV53092667; called by muse, mutect2, varscan2
- CIC | c.2214C>A p.T738= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV50559132; called by muse, mutect2, varscan2
- CLASP1 | c.3651C>T p.R1217= | Silent (SNP) | VAF 26/136 reads (19%) | catalogued as rs746947848, COSV55321358; called by muse, mutect2, varscan2
- CLTC | c.4579C>T p.L1527= | Silent (SNP) | VAF 54/149 reads (36%) | catalogued as COSV52246876; called by muse, mutect2, varscan2
- CNTNAP5 | c.1896G>A p.V632= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as COSV70482373; called by muse, mutect2, varscan2
- CYP2R1 | c.813G>A p.Q271= | Silent (SNP) | VAF 48/155 reads (31%) | catalogued as COSV100584835, COSV58127274; called by muse, mutect2, varscan2
- DCLK2 | c.1926G>A p.A642= | Silent (SNP) | VAF 65/172 reads (38%) | catalogued as rs755142772, COSV56202640; called by muse, mutect2, varscan2
- DCX | c.210C>T p.Y70= | Silent (SNP) | VAF 157/398 reads (39%) | catalogued as COSV57568241, COSV57570199; called by muse, mutect2, varscan2
- DENND4B | c.168A>G p.A56= | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV57842190; called by muse, mutect2, varscan2
- DGKK | c.2217C>T p.D739= | Silent (SNP) | VAF 82/475 reads (17%) | catalogued as COSV65707102; called by muse, mutect2, varscan2
- DGUOK | c.646C>T p.L216= | Silent (SNP) | VAF 54/143 reads (38%) | catalogued as rs1434900102, COSV51203454, COSV51204796; called by muse, mutect2, varscan2
- DISP2 | c.2787C>T p.H929= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as COSV51119535; called by muse, mutect2, varscan2
- DNAH5 | c.1911T>C p.I637= | Silent (SNP) | VAF 63/142 reads (44%) | catalogued as COSV54218505; called by muse, mutect2, varscan2
- DNAJC13 | c.549G>A p.A183= | Silent (SNP) | VAF 42/100 reads (42%) | catalogued as rs528705790, COSV53449141; called by muse, mutect2, varscan2
- DPYSL2 | c.771C>T p.S257= | Silent (SNP) | VAF 44/113 reads (39%) | catalogued as COSV60782993; called by muse, mutect2
- DUSP21 | c.246C>T p.Y82= | Silent (SNP) | VAF 81/207 reads (39%) | catalogued as rs369441582, COSV59133653; called by muse, mutect2, varscan2
- DYNC1H1 | c.2118G>A p.V706= | Silent (SNP) | VAF 27/81 reads (33%) | catalogued as COSV64136142; called by muse, mutect2, varscan2
- EGFL8 | c.321G>A p.A107= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as rs150029816; called by muse, mutect2, varscan2
- ENC1 | c.123G>A p.Q41= | Silent (SNP) | VAF 27/68 reads (40%) | catalogued as rs1370928554, COSV56629331; called by muse, mutect2, varscan2
- ENPEP | c.162G>A p.A54= | Silent (SNP) | VAF 65/176 reads (37%) | catalogued as rs761812461, COSV54447909; called by muse, mutect2, varscan2
- FCRL5 | c.1113C>A p.L371= | Silent (SNP) | VAF 37/102 reads (36%) | catalogued as COSV62513461; called by muse, mutect2, varscan2
- FICD | c.130C>T p.L44= | Silent (SNP) | VAF 17/42 reads (40%) | catalogued as COSV64200745, COSV64200747; called by muse, mutect2, varscan2
- FREM1 | c.724C>T p.L242= | Silent (SNP) | VAF 9/293 reads (3%) | catalogued as COSV66521993; called by muse, mutect2
- FRMPD1 | c.4467C>T p.A1489= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs147577823, COSV66700049; called by muse, mutect2, varscan2
- FYCO1 | c.2044C>T p.L682= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV56115313; called by muse, mutect2, varscan2
- GAPVD1 | c.2325T>C p.S775= | Silent (SNP) | VAF 70/150 reads (47%) | catalogued as COSV52922314; called by muse, mutect2, varscan2
- GMPR | c.150C>T p.I50= | Silent (SNP) | VAF 87/197 reads (44%) | catalogued as COSV52473099; called by muse, mutect2, varscan2
- GPKOW | c.546C>T p.G182= | Silent (SNP) | VAF 61/132 reads (46%) | catalogued as COSV50242469; called by muse, mutect2, varscan2
- GRIK1 | c.1803C>A p.P601= | Silent (SNP) | VAF 76/195 reads (39%) | catalogued as COSV58715872; called by muse, mutect2, varscan2
- GRIN2C | c.1701G>A p.V567= | Silent (SNP) | VAF 58/125 reads (46%) | catalogued as rs759891692, COSV53111545; called by muse, mutect2, varscan2
- HCFC1 | c.4845G>A p.T1615= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as rs782697777, COSV60071460; called by muse, mutect2, varscan2
- HCFC1 | c.2823A>G p.A941= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as COSV60071471; called by muse, mutect2, varscan2
- HDAC10 | c.1131G>A p.R377= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV50541769; called by muse, mutect2, varscan2
- HERC2 | c.948G>A p.L316= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV55319018; called by muse, mutect2, varscan2
- HRC | c.999A>G p.S333= | Silent (SNP) | VAF 68/404 reads (17%) | catalogued as COSV53255977; called by muse, mutect2, varscan2
- HTT | c.7911C>T p.D2637= | Silent (SNP) | VAF 45/92 reads (49%) | catalogued as rs768674350, COSV61860602; called by muse, mutect2, varscan2
- IFT74 | c.1290T>C p.T430= | Silent (SNP) | VAF 51/131 reads (39%) | catalogued as COSV66286570; called by muse, mutect2, varscan2
- IGHV2-5 | c.354C>T p.H118= | Silent (SNP) | VAF 49/277 reads (18%) | called by muse, mutect2, varscan2
- IGSF9 | c.2472C>T p.A824= (on ENST00000368094 / NM_001135050.2; = p.A808= on NM_020789.4) | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as rs1365517073, COSV57422041; called by muse, mutect2, varscan2
- IKZF3 | c.837C>T p.R279= | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as COSV53100387, COSV53101386; called by muse, mutect2, varscan2
- INTS11 | c.1617G>A p.K539= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV60088026; called by muse, mutect2
- ITGA5 | c.2235T>C p.G745= | Silent (SNP) | VAF 18/243 reads (7%) | catalogued as COSV53217133; called by muse, mutect2
- JPH1 | c.48C>T p.G16= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as COSV60610175, COSV60614303; called by muse, mutect2
- JUP | c.891C>T p.Y297= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as rs397517302, COSV60277689; ClinVar: likely benign; called by muse, mutect2, varscan2
- KCNK5 | c.1449C>T p.Y483= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as rs1374647823, COSV63988795; called by muse, mutect2, varscan2
- KDM5A | c.2022G>A p.R674= | Silent (SNP) | VAF 62/150 reads (41%) | catalogued as rs749436300, COSV66991820; called by muse, mutect2, varscan2
- KIAA1549L | c.4669C>T p.L1557= (on ENST00000321505; = p.L1854= on NM_012194.3) | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs539858967, COSV58586274; called by muse, mutect2, varscan2
- KIF21B | c.2892G>A p.L964= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV59756023; called by muse, mutect2, varscan2
- KIF26B | c.642C>T p.Y214= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs751658390, COSV68572319; called by muse, mutect2, varscan2
- KLHL24 | c.1122C>T p.S374= | Silent (SNP) | VAF 86/222 reads (39%) | catalogued as COSV54425761; called by muse, mutect2, varscan2
- KMT2D | c.15513G>A p.R5171= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as COSV56429878; called by muse, mutect2, varscan2
- KY | c.1326C>T p.V442= | Silent (SNP) | VAF 31/77 reads (40%) | catalogued as COSV71017044; called by muse, mutect2, varscan2
- LDLRAP1 | c.894C>T p.S298= | Silent (SNP) | VAF 10/28 reads (36%) | catalogued as rs747886166, COSV65473274; called by muse, mutect2, varscan2
- MAB21L2 | c.651G>A p.S217= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as COSV58261524; called by muse, mutect2, varscan2
- MFGE8 | c.135G>A p.V45= | Silent (SNP) | VAF 56/157 reads (36%) | catalogued as rs150866490; called by muse, mutect2, varscan2
- MGAT2 | c.771C>T p.F257= | Silent (SNP) | VAF 28/177 reads (16%) | catalogued as COSV53565895; called by muse, mutect2, varscan2
- MID2 | c.627T>C p.S209= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV53308680; called by muse, mutect2, varscan2
- MROH9 | c.1074G>A p.V358= | Silent (SNP) | VAF 123/255 reads (48%) | catalogued as COSV63010868; called by muse, mutect2, varscan2
- MYL2 | c.435C>T p.D145= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as rs766907447, COSV57406788; called by muse, mutect2, varscan2
- NFRKB | c.2238C>T p.S746= (on ENST00000446488 / NM_001143835.2; = p.S771= on NM_006165.3) | Silent (SNP) | VAF 157/392 reads (40%) | catalogued as rs762626664, COSV58757554; called by muse, mutect2, varscan2
- NIBAN3 | c.289C>A p.R97= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as COSV56308012; called by muse, mutect2, varscan2
- NPHS1 | c.1884C>T p.A628= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV62287396; called by muse, mutect2, varscan2
- NSDHL | c.456C>T p.G152= | Silent (SNP) | VAF 131/326 reads (40%) | catalogued as rs1034610164, COSV64743362; called by muse, mutect2, varscan2
- NTM | c.312C>T p.N104= | Silent (SNP) | VAF 57/133 reads (43%) | catalogued as rs369115555, COSV66172278, COSV99058462; called by muse, mutect2, varscan2
- OR10A3 | c.582A>G p.L194= | Silent (SNP) | VAF 78/165 reads (47%) | catalogued as COSV100660328, COSV62459396; called by muse, mutect2, varscan2
- PCDHB13 | c.1917G>A p.R639= | Silent (SNP) | VAF 8/14 reads (57%) | catalogued as COSV53395441; called by muse, varscan2
- PGBD5 | c.1056G>A p.P352= (on ENST00000525115; = p.P421= on NM_001258311.2) | Silent (SNP) | VAF 61/163 reads (37%) | catalogued as rs1372786140, COSV58411281; called by muse, mutect2, varscan2
- PIRT | c.111C>T p.S37= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs753417937, COSV74119876; called by muse, mutect2, varscan2
- PODXL | c.1185C>T p.C395= (on ENST00000378555 / NM_001018111.3; = p.C363= on NM_005397.4) | Silent (SNP) | VAF 24/164 reads (15%) | catalogued as rs748107948, COSV59869765; called by muse, varscan2
- POLA2 | c.826C>A p.R276= | Silent (SNP) | VAF 114/262 reads (44%) | catalogued as COSV55482414; called by muse, mutect2, varscan2
- POU4F2 | c.1077G>A p.S359= | Silent (SNP) | VAF 23/56 reads (41%) | catalogued as rs746344869, COSV55583836, COSV55584848; called by muse, mutect2, varscan2
- PPP1R15A | c.1974C>T p.R658= | Silent (SNP) | VAF 18/45 reads (40%) | catalogued as rs1207588530, COSV52338720; called by muse, mutect2, varscan2
- PPP1R16A | c.303C>T p.N101= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs199683628, COSV52952865; called by muse, mutect2, varscan2
- PPP5C | c.1477C>T p.L493= | Silent (SNP) | VAF 27/84 reads (32%) | catalogued as COSV50139797; called by muse, mutect2, varscan2
- PRKAG1 | c.384G>A p.P128= | Silent (SNP) | VAF 24/162 reads (15%) | catalogued as rs200112961, COSV60292342; called by muse, mutect2, varscan2
- PRKCQ | c.1386C>T p.N462= | Silent (SNP) | VAF 77/229 reads (34%) | catalogued as rs773438094, COSV54107112; called by muse, mutect2, varscan2
- PRKD1 | c.1218C>T p.L406= | Silent (SNP) | VAF 71/598 reads (12%) | catalogued as rs1345511846, COSV59565535; called by muse, mutect2, varscan2
- PRRC2C | c.5163A>G p.R1721= (on ENST00000367742; = p.R1719= on NM_015172.4) | Silent (SNP) | VAF 61/160 reads (38%) | catalogued as COSV58904033; called by muse, mutect2, varscan2
- PRX | c.1599G>A p.V533= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV52529330; called by muse, mutect2, varscan2
- PTPN4 | c.1872T>C p.P624= | Silent (SNP) | VAF 63/121 reads (52%) | catalogued as COSV55300402; called by muse, mutect2, varscan2
- RABGGTA | c.957C>T p.R319= | Silent (SNP) | VAF 36/119 reads (30%) | catalogued as rs372667304; called by muse, mutect2, varscan2
- RAD51B | c.555T>C p.C185= | Silent (SNP) | VAF 91/241 reads (38%) | catalogued as COSV66846602; called by muse, mutect2, varscan2
- RAPGEF2 | c.855A>G p.E285= | Silent (SNP) | VAF 91/216 reads (42%) | catalogued as COSV52426903; called by muse, mutect2, varscan2
- RASEF | c.1077C>T p.A359= | Silent (SNP) | VAF 202/496 reads (41%) | catalogued as COSV64586770; called by muse, mutect2, varscan2
- RBM15B | c.2229C>T p.D743= | Silent (SNP) | VAF 30/58 reads (52%) | catalogued as COSV60041738, COSV60042263; called by muse, mutect2, varscan2
- RBM6 | c.891G>A p.Q297= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as rs553069155, COSV56481971; called by muse, mutect2, varscan2
- RFTN1 | c.1452G>A p.Q484= | Silent (SNP) | VAF 122/285 reads (43%) | catalogued as COSV61918249; called by muse, mutect2
- RIMS4 | c.753G>A p.R251= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as COSV65719562; called by muse, mutect2, varscan2
- RNF10 | c.675C>T p.C225= | Silent (SNP) | VAF 94/223 reads (42%) | catalogued as COSV58044653; called by muse, mutect2, varscan2
- RNF220 | c.15G>A p.R5= | Silent (SNP) | VAF 33/84 reads (39%) | catalogued as COSV62406061; called by muse, mutect2, varscan2
- RNF41 | c.492G>T p.A164= | Silent (SNP) | VAF 65/154 reads (42%) | catalogued as COSV61504274; called by muse, mutect2, varscan2
- ROPN1B | c.612C>T p.T204= | Silent (SNP) | VAF 93/273 reads (34%) | catalogued as COSV52542054; called by muse, mutect2, varscan2
- ROR2 | c.1623C>T p.G541= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs746790764, COSV65216315; called by muse, mutect2, varscan2
- SEC24C | c.843A>G p.Q281= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as rs780222304, COSV59541365; called by muse, mutect2, varscan2
- SERPINI2 | c.633C>A p.V211= | Silent (SNP) | VAF 99/281 reads (35%) | catalogued as COSV52985724; called by muse, mutect2, varscan2
- SESN2 | c.1362C>T p.H454= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as rs776138760, COSV53427316; called by muse, mutect2, varscan2
- SH3BP5 | c.960C>A p.S320= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as COSV53743819, COSV99508181; called by muse, mutect2
- SLC19A1 | c.861C>T p.Y287= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs1346084661, COSV60754165; called by muse, mutect2, varscan2
- SLIT1 | c.1395C>T p.R465= | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs774875316, COSV56587322; called by muse, mutect2, varscan2
- SNRNP200 | c.5709G>A p.Q1903= | Silent (SNP) | VAF 136/329 reads (41%) | catalogued as COSV55530628; called by muse, mutect2, varscan2
- SNX8 | c.1029G>A p.Q343= | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV56126306; called by muse, mutect2, varscan2
- SNX8 | c.213G>C p.L71= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV56126318; called by muse, mutect2, varscan2
- SORCS2 | c.2866C>T p.L956= | Silent (SNP) | VAF 26/73 reads (36%) | catalogued as rs1437048901, COSV61165237; called by muse, mutect2, varscan2
- SPATA4 | c.714G>T p.V238= | Silent (SNP) | VAF 43/115 reads (37%) | catalogued as COSV54589552; called by muse, mutect2, varscan2
- STAP2 | c.555C>T p.D185= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as COSV55695682; called by muse, mutect2, varscan2
- STX2 | c.486C>T p.D162= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs201520117, COSV55432895; called by muse, mutect2, varscan2
- SVIL | c.5226C>T p.H1742= (on ENST00000355867 / NM_021738.3; = p.H1316= on NM_003174.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/93 reads (28%) | catalogued as rs748042633, COSV63442487; called by muse, mutect2, varscan2
- TAB2 | c.1116C>T p.S372= | Silent (SNP) | VAF 64/160 reads (40%) | catalogued as COSV53852163; called by muse, mutect2, varscan2
- TAF1B | c.309T>C p.D103= | Silent (SNP) | VAF 137/296 reads (46%) | catalogued as rs1468672942, COSV55155395; called by muse, mutect2, varscan2
- THAP9 | c.1467A>G p.A489= | Silent (SNP) | VAF 52/117 reads (44%) | catalogued as rs1053643548, COSV56356165; called by muse, mutect2, varscan2
- TNIK | c.2544C>T p.S848= | Silent (SNP) | VAF 172/410 reads (42%) | catalogued as rs769724807, COSV52675155, COSV99454937; called by muse, mutect2, varscan2
- TNRC6A | c.2043C>T p.R681= | Silent (SNP) | VAF 68/167 reads (41%) | catalogued as COSV59363150; called by muse, mutect2, varscan2
- TRAF2 | c.1158C>T p.Y386= | Silent (SNP) | VAF 32/65 reads (49%) | catalogued as rs565923793, COSV56037399; called by muse, mutect2, varscan2
- TRIM48 | c.312T>C p.S104= | Silent (SNP) | VAF 230/501 reads (46%) | catalogued as rs757260833, COSV70161393; called by muse, mutect2, varscan2
- TSC2 | c.654C>A p.S218= | Silent (SNP) | VAF 33/76 reads (43%) | catalogued as COSV54761955; called by muse, mutect2, varscan2
- TTC39B | c.861C>T p.N287= | Silent (SNP) | VAF 35/217 reads (16%) | catalogued as COSV52609457; called by muse, mutect2, varscan2
- TTN | c.6162C>T p.A2054= (on ENST00000591111; = p.A2008= on NM_003319.4) | Silent (SNP) | VAF 116/302 reads (38%) | catalogued as rs143265948; ClinVar: benign / likely benign; called by muse, mutect2, varscan2
- TUBA4A | c.924G>A p.R308= | Silent (SNP) | VAF 51/157 reads (32%) | catalogued as COSV50278064; called by muse, mutect2, varscan2
- UBL4B | c.507G>A p.E169= | Silent (SNP) | VAF 12/27 reads (44%) | catalogued as rs1286316681, COSV61944362; called by muse, mutect2, varscan2
- UGT2B7 | c.300T>C p.L100= | Silent (SNP) | VAF 74/199 reads (37%) | catalogued as COSV59442918; called by muse, mutect2, varscan2
- URI1 | c.1314G>A p.L438= | Silent (SNP) | VAF 79/189 reads (42%) | catalogued as COSV56349346; called by muse, mutect2, varscan2
- USP10 | c.2085T>G p.G695= | Silent (SNP) | VAF 108/300 reads (36%) | catalogued as COSV54748372; called by muse, mutect2, varscan2
- USP4 | c.798T>C p.T266= | Silent (SNP) | VAF 123/281 reads (44%) | catalogued as COSV55536300; called by muse, mutect2, varscan2
- WDR64 | c.2661C>T p.I887= | Silent (SNP) | VAF 50/140 reads (36%) | catalogued as rs778991362, COSV63794859; called by muse, mutect2, varscan2
- WFIKKN2 | c.108G>A p.P36= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs769127757, COSV60957713; called by muse, mutect2
- ZIC3 | c.375C>T p.S125= | Silent (SNP) | VAF 5/8 reads (63%) | catalogued as rs1205118611, COSV54973579; called by muse, mutect2, varscan2
- ZNF286A | c.1302A>G p.G434= | Silent (SNP) | VAF 112/267 reads (42%) | catalogued as COSV67845431; called by muse, mutect2, varscan2
- ZNF765 | c.861A>T p.T287= | Silent (SNP) | VAF 73/175 reads (42%) | catalogued as rs1172155381, COSV67182280, COSV67183477; called by muse, mutect2, varscan2
- ZSCAN10 | c.12G>T p.R4= (on ENST00000252463; = p.R59= on NM_032805.3) | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV52967610; called by muse, mutect2, varscan2
- BNIP1 | c.178-2762_178-2714delinsAGCCAGTTCTCTATCAAAGGGCATTTATTTGGACTGCTTCCACA | Intron (DEL) | VAF 22/265 reads (8%) | called by pindel, varscan2*
- COMMD9 | chr11:36271664 G>A | 3'Flank (SNP) | VAF 88/238 reads (37%) | catalogued as rs757794308; called by muse, mutect2, varscan2
- EHMT1 | chr9:137838509 del C | 3'Flank (DEL) | VAF 8/19 reads (42%) | catalogued as rs749169251; called by mutect2, pindel
- EIF5A | chr17:7307059 del G | 5'Flank (DEL) | VAF 57/132 reads (43%) | catalogued as rs1437481725; called by mutect2, pindel, varscan2
- GCNT2 | c.925+27347del | Intron (DEL) | VAF 39/136 reads (29%) | called by mutect2, pindel, varscan2
- GPM6B | chrX:13772984 T>C | 3'Flank (SNP) | VAF 174/420 reads (41%) | catalogued as COSV57422005; called by muse, mutect2, varscan2
- HAO2 | c.*7del | 3'UTR (DEL) | VAF 94/285 reads (33%) | called by mutect2, pindel, varscan2
- MGAM | c.4618+3231A>G | Intron (SNP) | VAF 7/178 reads (4%) | catalogued as COSV101527570; called by muse, mutect2
- MUC2 | c.*147del | 3'UTR (DEL) | VAF 23/83 reads (28%) | called by mutect2, pindel, varscan2
- PHKB | c.76+2552G>A | Intron (SNP) | VAF 110/291 reads (38%) | catalogued as rs746670187, COSV54519295; called by muse, mutect2, varscan2
- RFX7 | c.-259G>A | 5'UTR (SNP) | VAF 11/45 reads (24%) | catalogued as rs771109013, COSV57962284; called by muse, mutect2, varscan2
- RNF8 | c.*74G>A | 3'UTR (SNP) | VAF 73/155 reads (47%) | catalogued as COSV57721012; called by muse, mutect2, varscan2
- SYTL2 | c.1460-3354dup | Intron (INS) | VAF 72/214 reads (34%) | catalogued as rs767992187; called by mutect2, varscan2
- TMEM126B | c.*9del | 3'UTR (DEL) | VAF 22/77 reads (29%) | catalogued as rs1565794858; called by mutect2, pindel, varscan2
- WASF4P | n.933C>A | RNA (SNP) | VAF 40/240 reads (17%) | called by muse, mutect2, varscan2
